Somatic mutation profile of tumor specimen TCGA-ZF-AA51-01A (aliquot TCGA-ZF-AA51-01A-21D-A391-08) from TCGA case TCGA-ZF-AA51, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 69.8 years (25,484 days).
Specimen TCGA-ZF-AA51-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0d044928-2716-4238-a33d-83a09073f25a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZF-AA51-10A (Blood Derived Normal), aliquot TCGA-ZF-AA51-10A-01D-A394-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1b901948-9848-45dc-9023-df2c22ac5f45

The open-access MAF lists 758 somatic variants for this specimen: 553 protein-altering or splice-affecting, 179 silent, 26 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 471, Silent 179, Nonsense Mutation 58, Intron 8, Splice Site 7, RNA 5, Splice Region 5, Frame Shift Del 4, 3'Flank 4, 5'UTR 3, 3'UTR 3, In Frame Del 3.

Variants (750 of 758; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RYR1 | c.7111G>A p.E2371K | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.258); catalogued as rs1057518940, COSV100616431; ClinVar: pathogenic; called by muse, mutect2
- TP53 | c.880G>T p.E294* | Nonsense Mutation (SNP) | VAF 22/43 reads (51%) | hotspot (GDC flag); catalogued as rs1057520607, CM144128, COSV52689734, COSV52701760, COSV52773998, COSV53851434; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA12 | c.6900C>G p.F2300L (on ENST00000272895 / NM_173076.3; = p.F1982L on NM_015657.3) | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as CM164695, COSV55952790; called by muse, mutect2, varscan2
- ABCA12 | c.5955C>G p.I1985M (on ENST00000272895 / NM_173076.3; = p.I1667M on NM_015657.3) | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.664); catalogued as COSV55952806; called by muse, mutect2, varscan2
- ABCA6 | c.1442G>C p.R481T | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV52636769; called by muse, mutect2, varscan2
- ABCC12 | c.3252C>G p.F1084L | Missense Mutation (SNP) | VAF 68/140 reads (49%) | SIFT tolerated (0.12); PolyPhen benign (0.102); catalogued as COSV60912574; called by muse, mutect2, varscan2
- ABCC5 | c.1168C>T p.R390W | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as rs770158731, COSV55588274; called by muse, mutect2, varscan2
- ABCF2 | c.463G>A p.D155N | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.013); catalogued as COSV55181500, COSV99734827; called by muse, mutect2, varscan2
- AC004593.2 | c.659C>G p.S220* | Nonsense Mutation (SNP) | VAF 8/58 reads (14%) | catalogued as COSV56099052, COSV99765643; called by muse, mutect2, varscan2
- AC008878.1 | c.119C>T p.S40L | Missense Mutation (SNP) | VAF 8/74 reads (11%) | PolyPhen possibly damaging (0.514); catalogued as COSV51174383; called by muse, mutect2, varscan2
- AC011462.1 | c.461A>G p.Y154C | Missense Mutation (SNP) | VAF 53/174 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs764284154, COSV54196252; called by muse, mutect2, varscan2
- ACCSL | c.14C>G p.S5* | Nonsense Mutation (SNP) | VAF 13/60 reads (22%) | catalogued as COSV101122251; called by muse, mutect2, varscan2
- ACTN1 | c.2279G>A p.R760Q | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs757704267, COSV51989505; called by muse, mutect2, varscan2
- ADAM18 | c.577G>C p.E193Q | Missense Mutation (SNP) | VAF 21/247 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.864); catalogued as COSV55845273, COSV55856487; called by muse, mutect2
- ADAM18 | c.1324G>C p.E442Q | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT tolerated (0.48); PolyPhen benign (0.01); catalogued as COSV55845281; called by mutect2, varscan2
- ADAMTS12 | c.514G>A p.G172R | Missense Mutation (SNP) | VAF 31/123 reads (25%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.901); catalogued as COSV61258261; called by muse, mutect2, varscan2
- ADCY4 | c.264G>A p.W88* | Nonsense Mutation (SNP) | VAF 4/18 reads (22%) | catalogued as COSV99353350; called by muse, mutect2
- ADCY5 | c.2638C>T p.H880Y | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.86); PolyPhen benign (0.005); catalogued as COSV59195688; called by muse, mutect2, varscan2
- ADGRB2 | c.811G>C p.D271H | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV57071637; called by muse, mutect2, varscan2
- ADGRE1 | c.2334G>C p.Q778H | Missense Mutation (SNP) | VAF 26/146 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); catalogued as rs1232195658, COSV51673281; called by muse, mutect2, varscan2
- ADGRG4 | c.7513G>C p.E2505Q | Missense Mutation (SNP) | VAF 9/96 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.53); catalogued as COSV54951910; called by muse, mutect2
- ADGRG6 | c.3184G>A p.E1062K | Missense Mutation (SNP) | VAF 40/155 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.988); catalogued as COSV51588413; called by muse, mutect2, varscan2
- AGBL5 | c.151G>A p.D51N | Missense Mutation (SNP) | VAF 41/128 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.663); catalogued as COSV59935823; called by muse, mutect2, varscan2
- AGL | c.557C>G p.S186* | Nonsense Mutation (SNP) | VAF 31/121 reads (26%) | catalogued as COSV99649724; called by muse, mutect2, varscan2
- AHNAK | c.11575C>A p.P3859T | Missense Mutation (SNP) | VAF 48/240 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.167); catalogued as COSV57207480; called by muse, mutect2, varscan2
- AICDA | c.511C>A p.R171S | Missense Mutation (SNP) | VAF 31/186 reads (17%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.605); catalogued as COSV57563722, COSV57563879; called by muse, mutect2, varscan2
- AKAP17A | c.1775G>A p.G592E | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.44); catalogued as COSV100002386; called by muse, mutect2
- AKAP9 | c.6791C>G p.S2264C (on ENST00000359028; = p.S2240C on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV62341463; called by muse, mutect2, varscan2
- ALDH3A2 | c.565G>T p.V189F | Missense Mutation (SNP) | VAF 28/122 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV51565996; called by muse, mutect2, varscan2
- AMPH | c.1291C>T p.P431S | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.054); catalogued as rs1300102066, COSV57737024; called by muse, mutect2, varscan2
- ANAPC1 | c.1749C>A p.Y583* | Nonsense Mutation (SNP) | VAF 61/215 reads (28%) | catalogued as COSV100594946; called by muse, mutect2, varscan2
- ANKRD26 | c.5115G>C p.K1705N | Missense Mutation (SNP) | VAF 22/172 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.112); catalogued as COSV65773572, COSV65774600; called by muse, mutect2, varscan2
- ANO5 | c.573C>A p.F191L | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV61083287; called by muse, mutect2, varscan2
- AP002512.3 | c.1046C>T p.T349M | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT tolerated (0.16); PolyPhen benign (0.342); catalogued as rs558210028, COSV54405409; called by muse, mutect2, varscan2
- APC2 | c.3184G>C p.E1062Q | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.043); catalogued as rs1055395523, COSV52016803; called by muse, mutect2, varscan2
- APOBEC4 | c.1098G>C p.K366N | Missense Mutation (SNP) | VAF 19/123 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV58017080, COSV58017709; called by muse, mutect2, varscan2
- AQP1 | c.338C>G p.S113* | Nonsense Mutation (SNP) | VAF 40/108 reads (37%) | catalogued as COSV61266810, COSV61267959, COSV61268717; called by muse, mutect2, varscan2
- ARHGAP33 | c.3065C>G p.S1022C | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.937); catalogued as COSV50120176; called by muse, varscan2
- ARHGAP33 | c.3118C>A p.P1040T | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.154); catalogued as COSV50120200; called by muse, varscan2
- ARID1A | c.2032C>T p.Q678* | Nonsense Mutation (SNP) | VAF 22/81 reads (27%) | catalogued as COSV61379976; called by muse, mutect2, varscan2
- ARID1A | c.5998G>C p.E2000Q | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV61373949; called by muse, mutect2, varscan2
- ARID1B | c.3331G>A p.E1111K | Missense Mutation (SNP) | VAF 39/88 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51653717; called by muse, mutect2, varscan2
- ARMC4 | c.1951C>G p.P651A | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.952); catalogued as COSV59459316; called by muse, mutect2, varscan2
- ASB16 | c.589G>T p.E197* | Nonsense Mutation (SNP) | VAF 25/85 reads (29%) | catalogued as COSV99518998; called by muse, mutect2, varscan2
- ASB3 | c.240C>G p.F80L | Missense Mutation (SNP) | VAF 68/124 reads (55%) | SIFT tolerated (0.67); PolyPhen benign (0.013); catalogued as COSV55074501; called by muse, mutect2, varscan2
- ASCC3 | c.41C>T p.S14L | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.038); catalogued as COSV61226734; called by muse, mutect2
- ASPM | c.4850G>T p.R1617L | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV54126742, COSV54136170; called by muse, mutect2, varscan2
- ASTN2 | c.1743G>C p.K581N (on ENST00000313400 / NM_001365069.1; = p.K530N on NM_014010.5) | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.738); catalogued as COSV57760866; called by muse, mutect2, varscan2
- ATP4B | c.838G>C p.E280Q | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.999); catalogued as COSV100089809, COSV58928651; called by muse, mutect2
- ATP5MF-PTCD1 | c.25G>A p.D9N | Missense Mutation (SNP) | VAF 24/131 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.234); catalogued as rs1318369387, COSV52853986; called by muse, mutect2, varscan2
- ATXN1 | c.928G>A p.E310K | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.411); catalogued as rs1046225950, COSV55211642; called by muse, mutect2, varscan2
- AURKC | c.929G>C p.*310Sext*39 (on ENST00000302804 / NM_001015878.2; = p.*276Sext*39 on NM_003160.3) | Nonstop Mutation (SNP) | VAF 48/114 reads (42%) | catalogued as COSV100248928; called by muse, mutect2, varscan2
- BAZ2A | c.4323G>A p.W1441* | Nonsense Mutation (SNP) | VAF 5/19 reads (26%) | catalogued as COSV99466997; called by muse, mutect2, varscan2
- BCAT2 | c.324C>G p.F108L | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.276); catalogued as COSV60272031; called by muse, mutect2, varscan2
- BCORL1 | c.3360G>T p.K1120N | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); catalogued as COSV54392079; called by mutect2, varscan2
- BEND6 | c.383C>G p.S128C | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.189); catalogued as COSV66068392; called by muse, mutect2, varscan2
- BEST4 | c.11C>T p.S4L | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as rs1211861078, COSV100944031; called by muse, mutect2
- BMPER | c.329A>G p.Y110C | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.145); catalogued as rs1316332813, COSV51814103; called by muse, mutect2, varscan2
- BNIPL | c.913C>G p.L305V | Missense Mutation (SNP) | VAF 68/154 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.046); catalogued as COSV54846238; called by muse, mutect2, varscan2
- BOD1L1 | c.5752G>C p.E1918Q | Missense Mutation (SNP) | VAF 67/112 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); catalogued as COSV50008203; called by muse, mutect2, varscan2
- BOD1L1 | c.2005G>A p.E669K | Missense Mutation (SNP) | VAF 42/286 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.441); catalogued as rs1212092811, COSV50008220; called by muse, mutect2, varscan2
- BPIFB6 | c.1080C>A p.F360L | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as COSV62754637; called by muse, mutect2, varscan2
- BRAF | c.2026C>T p.Q676* (on ENST00000288602 / NM_001374244.1; = p.Q636* on NM_004333.6 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 12/42 reads (29%) | catalogued as COSV56115473, COSV56376383; called by muse, mutect2, varscan2
- BST1 | c.308G>A p.R103K | Missense Mutation (SNP) | VAF 53/94 reads (56%) | SIFT tolerated (0.94); PolyPhen benign (0.006); catalogued as COSV53945979; called by muse, varscan2
- BTN3A3 | c.870G>A p.M290I | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.29); PolyPhen benign (0.015); catalogued as COSV55071202; called by muse, mutect2, varscan2
- BUB3 | c.473G>C p.R158T | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT tolerated (0.45); PolyPhen benign (0.005); catalogued as COSV64363606; called by muse, mutect2, varscan2
- BUD31 | c.215G>A p.R72K | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT tolerated (0.94); PolyPhen benign (0.075); catalogued as COSV52860387, COSV52861879; called by muse, mutect2, varscan2
- C12orf40 | c.148G>C p.D50H | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61130322; called by muse, mutect2, varscan2
- C19orf73 | c.215C>T p.S72F | Missense Mutation (SNP) | VAF 38/70 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as COSV55521243; called by muse, varscan2
- C1orf116 | c.337G>C p.E113Q | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as COSV63943864, COSV63943943; called by muse, mutect2, varscan2
- C1orf131 | c.356C>A p.S119Y | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.563); catalogued as COSV59642002; called by muse, mutect2, varscan2
- C1orf52 | c.88G>A p.E30K | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs1288725873, COSV53998458; called by muse, mutect2, varscan2
- C1orf56 | c.404C>T p.S135F | Missense Mutation (SNP) | VAF 37/69 reads (54%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV54846255; called by muse, mutect2, varscan2
- C2orf80 | c.353C>T p.S118F | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.555); catalogued as COSV100378266, COSV58015998; called by muse, mutect2, varscan2
- C3orf56 | c.491C>T p.S164L | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.437); catalogued as rs776931204, COSV101228983, COSV67756072; called by muse, mutect2, varscan2
- CASC3 | c.1267G>A p.E423K | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.104); catalogued as COSV52866695; called by muse, mutect2, varscan2
- CBLN2 | c.325A>T p.S109C | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV54050659; called by muse, mutect2, varscan2
- CCDC157 | c.2131G>T p.E711* | Nonsense Mutation (SNP) | VAF 19/81 reads (23%) | catalogued as COSV99306636; called by muse, varscan2
- CCDC173 | c.1535G>C p.R512T | Missense Mutation (SNP) | VAF 44/121 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.563); catalogued as COSV53641932, COSV53644818; called by muse, varscan2
- CCDC173 | c.1427G>A p.R476K | Missense Mutation (SNP) | VAF 80/200 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV53641938, COSV53645588; called by muse, varscan2
- CCDC30 | c.530G>A p.R177Q (on ENST00000340612; = p.R134Q on NM_001080850.3) | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs771159252, COSV59605287; called by muse, mutect2
- CCNT1 | c.484C>T p.Q162* | Nonsense Mutation (SNP) | VAF 36/189 reads (19%) | catalogued as COSV99980841; called by muse, mutect2, varscan2
- CD82 | c.487G>A p.E163K | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (0.87); PolyPhen benign (0.077); catalogued as COSV57034278; called by muse, mutect2, varscan2
- CDCA2 | c.425G>T p.R142I | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV57944981; called by muse, mutect2, varscan2
- CDH10 | c.1978G>A p.E660K | Missense Mutation (SNP) | VAF 23/145 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52574477; called by muse, mutect2, varscan2
- CEP128 | c.1558C>T p.Q520* | Nonsense Mutation (SNP) | VAF 20/76 reads (26%) | catalogued as rs1370427497, COSV99825425; called by muse, mutect2, varscan2
- CEP128 | c.985C>G p.Q329E | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.825); catalogued as COSV53673366; called by muse, mutect2, varscan2
- CEP290 | c.6703G>A p.E2235K | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as COSV100469326; called by muse, mutect2
- CHCHD5 | c.307G>C p.E103Q | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV61424293; called by muse, mutect2, varscan2
- CHD2 | c.3630C>G p.I1210M | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.548); catalogued as COSV67707460; called by muse, mutect2, varscan2
- CHD2 | c.4693-2A>T p.X1565_splice | Splice Site (SNP) | VAF 10/44 reads (23%) | catalogued as COSV67707469; called by muse, mutect2, varscan2
- CHEK2 | c.718A>C p.K240Q (on ENST00000382580 / NM_001005735.2; = p.K197Q on NM_007194.4) | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.511); catalogued as COSV60417506; called by muse, varscan2
- CHRDL1 | c.1243G>A p.E415K (on ENST00000372045; = p.E421K on NM_145234.4) | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.037); catalogued as rs776899237, COSV54323694; called by muse, mutect2, varscan2
- CILK1 | c.488G>C p.R163T | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63153742; called by muse, mutect2, varscan2
- CLEC12B | c.388G>A p.E130K | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.412); catalogued as COSV58863012; called by muse, mutect2, varscan2
- CLEC14A | c.1239G>C p.L413F | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60562057; called by muse, mutect2, varscan2
- CLECL1 | c.251T>C p.V84A | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); catalogued as COSV59931156; called by muse, mutect2, varscan2
- CLP1 | c.114G>C p.L38F | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.569); catalogued as COSV57054095; called by muse, mutect2, varscan2
- CNNM4 | c.1712C>G p.S571* | Nonsense Mutation (SNP) | VAF 5/65 reads (8%) | catalogued as COSV100998762; called by muse, mutect2
- CNTF | c.138G>C p.K46N | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV60157956; called by muse, mutect2, varscan2
- CNTN2 | c.2556G>C p.W852C | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59348768; called by muse, mutect2, varscan2
- COG5 | c.2029-1G>C p.X677_splice (on ENST00000347053 / NM_001379512.1; = p.X698_splice on NM_006348.5 and 5 other RefSeq transcripts) | Splice Site (SNP) | VAF 37/94 reads (39%) | catalogued as COSV51745548; called by muse, mutect2, varscan2
- COL24A1 | c.2183C>A p.P728H | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.726); catalogued as rs1288353934, COSV65303846; called by muse, mutect2
- COL5A2 | c.2416C>G p.P806A | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.012); catalogued as COSV66408152; called by muse, mutect2, varscan2
- CORO1B | c.997G>C p.E333Q | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57048363; called by muse, mutect2, varscan2
- CPE | c.889C>T p.R297W | Missense Mutation (SNP) | VAF 133/277 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs202048102; called by muse, mutect2, varscan2
- CPSF3 | c.915C>G p.F305L | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV53008753; called by muse, mutect2, varscan2
- CPXM1 | c.1148G>T p.R383L | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.894); catalogued as COSV66044893; called by muse, mutect2, varscan2
- CRHBP | c.701C>T p.S234L | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV57187816; called by muse, mutect2, varscan2
- CTTNBP2 | c.2422G>C p.D808H | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.748); catalogued as COSV50392139; called by muse, mutect2, varscan2
- CUBN | c.3190T>G p.F1064V | Missense Mutation (SNP) | VAF 6/69 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as COSV64710732; called by muse, mutect2
- CUL4A | c.772G>C p.E258Q (on ENST00000375440 / NM_001008895.4; = p.E158Q on NM_003589.3) | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0.146); catalogued as COSV100417426; called by muse, mutect2, varscan2
- CXCL9 | c.207T>A p.N69K | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.574); catalogued as COSV53578494, COSV53578999; called by muse, mutect2, varscan2
- CYP3A7 | c.684C>A p.F228L | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.877); catalogued as rs201378266, COSV60480915; called by muse, mutect2, varscan2
- D2HGDH | c.1167C>G p.I389M | Missense Mutation (SNP) | VAF 18/131 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as COSV58319582; called by muse, mutect2, varscan2
- DCSTAMP | c.30C>G p.I10M | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.181); catalogued as COSV52576800; called by muse, mutect2, varscan2
- DDR1 | c.1597G>A p.A533T | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as rs138565451, COSV61320172; called by muse, mutect2, varscan2
- DDX18 | c.1648G>A p.E550K | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.066); catalogued as COSV54305781; called by muse, mutect2, varscan2
- DDX19B | c.173C>T p.A58V | Missense Mutation (SNP) | VAF 48/186 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.059); catalogued as COSV55363168; called by muse, mutect2
- DDX25 | c.479G>C p.R160T | Missense Mutation (SNP) | VAF 21/134 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.355); catalogued as COSV54989165; called by muse, mutect2, varscan2
- DDX3X | c.68C>T p.S23F | Missense Mutation (SNP) | VAF 19/114 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); catalogued as COSV67863072, COSV67863252; called by muse, mutect2, varscan2
- DHTKD1 | c.2045G>C p.G682A | Missense Mutation (SNP) | VAF 96/166 reads (58%) | SIFT tolerated (0.05); PolyPhen benign (0.023); catalogued as COSV53802403; called by muse, mutect2, varscan2
- DHX9 | c.3219G>C p.K1073N | Missense Mutation (SNP) | VAF 29/125 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.398); catalogued as COSV62358714; called by muse, mutect2, varscan2
- DIPK1A | c.19C>T p.P7S | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.001); catalogued as rs754017982, COSV100942189; called by muse, varscan2
- DLAT | c.1494G>A p.W498* | Nonsense Mutation (SNP) | VAF 17/90 reads (19%) | catalogued as COSV99734870; called by muse, varscan2
- DMBT1 | c.449C>G p.S150* | Nonsense Mutation (SNP) | VAF 39/188 reads (21%) | catalogued as COSV57543746; called by muse, mutect2, varscan2
- DNAH10 | c.5672C>T p.P1891L (on ENST00000409039; = p.P1830L on NM_207437.3) | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as rs1256501597, COSV68990082; called by muse, mutect2
- DNAH5 | c.4114C>T p.Q1372* | Nonsense Mutation (SNP) | VAF 4/36 reads (11%) | catalogued as COSV99452147; called by muse, mutect2
- DNAH9 | c.10947G>T p.Q3649H | Missense Mutation (SNP) | VAF 4/53 reads (8%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV99306980; called by muse, mutect2
- DNAJC3 | c.1081C>T p.Q361* | Nonsense Mutation (SNP) | VAF 7/29 reads (24%) | catalogued as rs1210937673, COSV100953418; called by muse, mutect2
- DNHD1 | c.13262C>T p.S4421L | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as rs368367159; called by muse, varscan2
- DNMT3L | c.28G>C p.E10Q | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.543); catalogued as COSV54263548; called by muse, mutect2
- DOCK9 | c.4071G>C p.M1357I (on ENST00000376460 / NM_001366676.2; = p.M1358I on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV100240222; called by muse, mutect2, varscan2
- DUS1L | c.543G>C p.Q181H | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV57648046, COSV57651082; called by muse, mutect2, varscan2
- DUSP8 | c.743C>G p.A248G | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.734); catalogued as COSV59029655; called by muse, mutect2, varscan2
- DUSP9 | c.1021G>T p.E341* | Nonsense Mutation (SNP) | VAF 52/133 reads (39%) | catalogued as COSV100720143; called by muse, mutect2, varscan2
- DYNC2H1 | c.12403G>C p.E4135Q | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.439); catalogued as COSV100518557, COSV62089496, COSV62108409; called by muse, mutect2, varscan2
- E2F1 | c.295C>T p.Q99* | Nonsense Mutation (SNP) | VAF 16/50 reads (32%) | catalogued as COSV100594057; called by muse, mutect2, varscan2
- EDRF1 | c.2271G>C p.Q757H (on ENST00000356792 / NM_001202438.2; = p.Q723H on NM_015608.2) | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.952); catalogued as COSV61762873; called by muse, mutect2, varscan2
- EFHD1 | c.622G>C p.E208Q | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1303843800, COSV51132031; called by muse, mutect2, varscan2
- EFNA4 | c.326C>T p.S109L | Missense Mutation (SNP) | VAF 28/119 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV55125782; called by muse, mutect2, varscan2
- EIF2AK3 | c.777C>G p.F259L | Missense Mutation (SNP) | VAF 33/72 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV100303985, COSV57545886; called by muse, mutect2, varscan2
- EML2 | c.1268C>T p.S423L | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.589); catalogued as COSV99840254; called by muse, mutect2, varscan2
- ENTPD3 | c.976G>C p.E326Q | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT tolerated (0.57); PolyPhen benign (0.122); catalogued as COSV57193714; called by muse, mutect2, varscan2
- EP300 | c.4519G>A p.D1507N | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54326633, COSV54329031; called by muse, mutect2, varscan2
- EP400 | c.4332C>A p.F1444L | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.009); catalogued as rs1307148438, COSV57766813; called by muse, mutect2, varscan2
- EPB41L2 | c.470C>A p.S157* | Nonsense Mutation (SNP) | VAF 56/238 reads (24%) | catalogued as COSV100441130; called by muse, mutect2, varscan2
- EPHA8 | c.1144G>A p.G382S | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.63); PolyPhen benign (0.125); catalogued as rs769118581, COSV51262922; called by muse, mutect2, varscan2
- EPHB6 | c.802G>C p.E268Q | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.021); catalogued as COSV101236013, COSV67417775; called by muse, mutect2, varscan2
- EPHX3 | c.645C>A p.F215L | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1172032034, COSV55654880; called by muse, mutect2, varscan2
- EPOR | c.842_844del p.K281del | In Frame Del (DEL) | VAF 8/80 reads (10%) | catalogued as rs781223562; called by pindel, varscan2
- ERCC2 | c.1660G>C p.E554Q | Missense Mutation (SNP) | VAF 40/88 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.142); catalogued as COSV67262824; called by muse, mutect2, varscan2
- ERCC6L | c.1162G>C p.D388H | Missense Mutation (SNP) | VAF 39/101 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV57819861; called by muse, mutect2, varscan2
- ESF1 | c.1072G>C p.D358H | Missense Mutation (SNP) | VAF 17/148 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52519796; called by muse, mutect2, varscan2
- ETV6 | c.317C>G p.S106C | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0.015); catalogued as COSV67148838; called by muse, mutect2, varscan2
- EVC2 | c.1054G>A p.D352N | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.111); catalogued as COSV60389788; called by muse, mutect2, varscan2
- EXOC2 | c.2104G>C p.D702H | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as COSV57862692; called by muse, mutect2, varscan2
- FAAH2 | c.1500C>G p.I500M | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.979); catalogued as COSV66506201; called by muse, mutect2, varscan2
- FABP1 | c.285C>G p.F95L | Missense Mutation (SNP) | VAF 18/152 reads (12%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV55558138; called by muse, mutect2, varscan2
- FAM193A | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 23/223 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as COSV61192210; called by muse, mutect2
- FAM214A | c.373G>C p.E125Q | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55922915, COSV55925007; called by muse, mutect2, varscan2
- FAM47C | c.1481G>C p.G494A | Missense Mutation (SNP) | VAF 21/128 reads (16%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.279); catalogued as COSV63724823; called by muse, mutect2, varscan2
- FAM47C | c.2549G>A p.R850K | Missense Mutation (SNP) | VAF 31/110 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.175); catalogued as COSV63724834; called by muse, mutect2, varscan2
- FAM71B | c.142G>C p.E48Q | Missense Mutation (SNP) | VAF 39/81 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs751570900, COSV57228090; called by muse, mutect2, varscan2
- FANCG | c.710C>G p.S237* | Nonsense Mutation (SNP) | VAF 24/62 reads (39%) | catalogued as COSV100734287; called by muse, mutect2, varscan2
- FAT4 | c.12594C>A p.Y4198* | Nonsense Mutation (SNP) | VAF 9/31 reads (29%) | catalogued as rs1487075437, COSV100629406; called by muse, mutect2, varscan2
- FEN1 | c.838C>T p.H280Y | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs764028854, COSV99952922; called by muse, mutect2, varscan2
- FGD6 | c.301C>G p.Q101E | Missense Mutation (SNP) | VAF 29/178 reads (16%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.007); catalogued as COSV59691359; called by muse, mutect2, varscan2
- FHOD1 | c.140G>A p.G47E | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as COSV99264333; called by muse, mutect2, varscan2
- FN1 | c.2098A>C p.T700P | Missense Mutation (SNP) | VAF 30/147 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.705); catalogued as COSV60548687; called by muse, mutect2, varscan2
- FN1 | c.1852G>C p.E618Q | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.804); catalogued as COSV60548699; called by muse, mutect2, varscan2
- FNDC3B | c.2250+1G>A p.X750_splice | Splice Site (SNP) | VAF 14/76 reads (18%) | catalogued as COSV61039266; called by muse, mutect2, varscan2
- FOXN3 | c.106C>T p.Q36* | Nonsense Mutation (SNP) | VAF 19/57 reads (33%) | catalogued as COSV99726906; called by muse, mutect2, varscan2
- FOXQ1 | c.541C>G p.L181V | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.905); catalogued as COSV57258696; called by muse, mutect2, varscan2
- FPGS | c.1314C>G p.F438L | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.307); catalogued as COSV100785327; called by muse, mutect2
- FTO | c.368C>T p.S123F | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.68); PolyPhen possibly damaging (0.48); catalogued as COSV67110725; called by muse, mutect2, varscan2
- GDPD2 | c.1006C>A p.P336T | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.986); catalogued as COSV100978670, COSV100978686; called by muse, mutect2
- GDPD4 | c.1242-1G>C p.X414_splice | Splice Site (SNP) | VAF 13/73 reads (18%) | catalogued as COSV100265528, COSV60017999; called by muse, mutect2, varscan2
- GLB1 | c.1015G>A p.E339K | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56562360; called by muse, mutect2, varscan2
- GLCE | c.143G>C p.R48T | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.018); catalogued as COSV55944905; called by muse, mutect2, varscan2
- GLI2 | c.3164C>T p.A1055V (on ENST00000361492 / NM_001374353.1; = p.A1072V on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.251); catalogued as rs1378085616, COSV58037241; called by muse, mutect2, varscan2
- GMFG | c.424C>T p.R142C | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.421); catalogued as rs1383405600, COSV53418973; called by muse, mutect2, varscan2
- GPBP1L1 | c.1396G>A p.E466K | Missense Mutation (SNP) | VAF 110/317 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.131); catalogued as COSV51967743; called by muse, mutect2, varscan2
- GPR158 | c.2596G>A p.E866K | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.124); catalogued as rs772059881, COSV100894027; called by muse, mutect2, varscan2
- GPR18 | c.107G>C p.G36A | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61621023; called by muse, mutect2, varscan2
- GPR31 | c.385C>T p.Q129* | Nonsense Mutation (SNP) | VAF 11/28 reads (39%) | catalogued as COSV100834162, COSV64761320; called by muse, mutect2, varscan2
- GPR63 | c.274C>G p.L92V | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs1323046555, COSV57740184; called by muse, mutect2, varscan2
- GPX7 | c.451C>T p.P151S | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.069); catalogued as COSV63652446; called by muse, mutect2, varscan2
- GTF3C1 | c.4154C>T p.S1385F | Missense Mutation (SNP) | VAF 55/105 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.438); catalogued as COSV62239743; called by muse, mutect2, varscan2
- H2BC4 | c.163A>G p.I55V | Missense Mutation (SNP) | VAF 33/166 reads (20%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.035); catalogued as COSV58415316; called by muse, mutect2, varscan2
- H4C13 | c.311G>C p.*104Sext*? | Nonstop Mutation (SNP) | VAF 11/36 reads (31%) | catalogued as rs1020190776, COSV100138001, COSV60695004; called by muse, mutect2, varscan2
- HCN1 | c.1807C>A p.Q603K | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.186); catalogued as COSV57499642, COSV57523847; called by muse, mutect2, varscan2
- HECTD4 | c.11281C>G p.P3761A | Missense Mutation (SNP) | VAF 26/40 reads (65%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.012); catalogued as COSV66388734; called by muse, mutect2, varscan2
- HECTD4 | c.11110G>C p.E3704Q | Missense Mutation (SNP) | VAF 24/44 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV66388743; called by muse, mutect2, varscan2
- HELQ | c.824G>A p.G275E | Missense Mutation (SNP) | VAF 56/153 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.393); catalogued as COSV55024546; called by muse, mutect2, varscan2
- HELZ | c.3964C>G p.P1322A | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.006); catalogued as COSV62377061; called by muse, varscan2
- HEPH | c.979C>A p.P327T (on ENST00000343002; = p.P60T on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100295271; called by muse, mutect2, varscan2
- HERC4 | c.1274A>C p.E425A | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.41); PolyPhen benign (0.017); catalogued as COSV53269375; called by muse, mutect2, varscan2
- HGS | c.475G>A p.D159N | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.113); catalogued as COSV61267072; called by muse, mutect2, varscan2
- HID1 | c.1212C>G p.F404L | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.099); catalogued as COSV59351215; called by muse, mutect2, varscan2
- HIVEP1 | c.6151G>C p.D2051H | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65099711; called by muse, mutect2, varscan2
- HNRNPUL1 | c.2193G>C p.K731N | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.354); catalogued as rs1478002945, COSV54560959; called by muse, mutect2, varscan2
- HPS1 | c.598G>A p.E200K | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.112); catalogued as rs370788424; called by muse, mutect2
- HPX | c.270G>A p.W90* | Nonsense Mutation (SNP) | VAF 18/67 reads (27%) | catalogued as rs1417215792, COSV56420383, COSV99793444; called by muse, mutect2, varscan2
- IDI2 | c.76G>A p.E26K | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as rs748040882, COSV52987367; called by muse, varscan2
- IFI44 | c.439G>C p.E147Q | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1219261640, COSV66074308; called by muse, mutect2, varscan2
- IGKJ4 | c.13G>A p.G5R | Missense Mutation (SNP) | VAF 36/71 reads (51%) | PolyPhen benign (0.035); catalogued as rs377607318; called by muse, mutect2, varscan2
- IGKV1-12 | c.9G>A p.M3I | Missense Mutation (SNP) | VAF 30/400 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.048); catalogued as rs1247949372; called by muse, mutect2
- IGSF10 | c.7738G>A p.G2580R | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.083); catalogued as rs1560167730, COSV56372640; called by muse, mutect2, varscan2
- IL16 | c.2701G>A p.E901K (on ENST00000302987 / NM_172217.5; = p.E200K on NM_004513.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs890824074, COSV57261612; called by muse, mutect2, varscan2
- IMPACT | c.821G>T p.G274V | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52421515; called by muse, mutect2, varscan2
- INF2 | c.2551G>A p.E851K | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.06); catalogued as rs776939784, COSV53030992; called by muse, mutect2, varscan2
- INTS6L | c.652C>A p.Q218K | Missense Mutation (SNP) | VAF 55/200 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV66083911; called by muse, mutect2, varscan2
- IPO7 | c.3047G>T p.G1016V | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as COSV101121838; called by muse, varscan2
- IQGAP2 | c.2305G>C p.D769H | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.589); catalogued as COSV57170029; called by muse, mutect2, varscan2
- IRX1 | c.1286C>T p.S429L | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs1336549298, COSV57359547; called by muse, mutect2
- ITGA4 | c.2974C>G p.L992V | Missense Mutation (SNP) | VAF 30/115 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.368); catalogued as COSV100183540, COSV59205054; called by muse, mutect2, varscan2
- ITGA8 | c.2407C>G p.H803D | Missense Mutation (SNP) | VAF 61/124 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.122); catalogued as COSV65226466, COSV65229743; called by muse, mutect2, varscan2
- ITGAX | c.2953G>A p.D985N | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.55); PolyPhen benign (0.034); catalogued as COSV51643076; called by muse, varscan2
- JCHAIN | c.223C>T p.P75S | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54658327; called by muse, mutect2, varscan2
- KALRN | c.6820G>A p.E2274K (on ENST00000360013 / NM_001024660.4; = p.E577K on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT tolerated (0.49); PolyPhen benign (0.168); catalogued as COSV52252154; called by muse, mutect2, varscan2
- KANK4 | c.2533G>C p.E845Q | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.653); catalogued as rs1487403981, COSV100443322, COSV58092222; called by muse, mutect2, varscan2
- KANK4 | c.2410G>A p.E804K | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.278); catalogued as rs371517518; called by muse, varscan2
- KAT6A | c.2281C>T p.Q761* | Nonsense Mutation (SNP) | VAF 7/147 reads (5%) | catalogued as COSV55911269, COSV99705591; called by muse, mutect2
- KAT6B | c.1781G>C p.R594T | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.395); catalogued as COSV54744262; called by muse, mutect2, varscan2
- KCNAB3 | c.468C>G p.I156M | Missense Mutation (SNP) | VAF 49/94 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV58049969; called by muse, mutect2, varscan2
- KCNC2 | c.1589A>G p.N530S | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV54365146; called by muse, mutect2, varscan2
- KCNH7 | c.266C>G p.S89* | Nonsense Mutation (SNP) | VAF 24/64 reads (38%) | catalogued as COSV100036938, COSV59815024; called by muse, mutect2, varscan2
- KCNJ2 | c.167T>C p.V56A | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV54660611; called by muse, mutect2, varscan2
- KCNK13 | c.756G>C p.E252D | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.42); PolyPhen benign (0.005); catalogued as COSV56411606, COSV99965487; called by muse, mutect2, varscan2
- KCNK2 | c.17C>A p.S6* | Nonsense Mutation (SNP) | VAF 16/52 reads (31%) | catalogued as COSV101222263, COSV67204276, COSV67204289; called by muse, mutect2, varscan2
- KCTD6 | c.440C>G p.T147S | Missense Mutation (SNP) | VAF 17/166 reads (10%) | SIFT tolerated (0.68); PolyPhen benign (0.188); catalogued as rs926373903, COSV57148020; called by muse, mutect2
- KDM2A | c.3321G>C p.L1107F | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV100445349, COSV58188996; called by muse, mutect2, varscan2
- KDM6A | c.616del p.E206Kfs*36 | Frame Shift Del (DEL) | VAF 21/121 reads (17%) | catalogued as COSV100937902, COSV65038316, COSV65045261; called by mutect2, pindel, varscan2
- KEL | c.28G>C p.E10Q | Missense Mutation (SNP) | VAF 36/190 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.079); catalogued as COSV62333981; called by muse, mutect2, varscan2
- KIF21B | c.1243G>A p.E415K | Missense Mutation (SNP) | VAF 27/147 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.257); catalogued as COSV100144596, COSV59754367, COSV59769096; called by muse, mutect2, varscan2
- KIF26B | c.5757C>G p.S1919R | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100832965; called by muse, mutect2
- KIF27 | c.2273C>G p.S758C | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.921); catalogued as COSV52826217, COSV52830400; called by muse, mutect2, varscan2
- KIF4B | c.3040C>G p.P1014A | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.08); catalogued as COSV70528449; called by muse, mutect2, varscan2
- KIF5A | c.610C>G p.R204G | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as CM083712, COSV54052618; called by muse, mutect2, varscan2
- KLHL41 | c.85G>A p.E29K | Missense Mutation (SNP) | VAF 26/140 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.777); catalogued as COSV52929709; called by muse, mutect2, varscan2
- KLKB1 | c.569C>T p.S190L | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52994555; called by muse, mutect2, varscan2
- KMT2C | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.321); catalogued as rs1308025847, COSV100074579; called by muse, mutect2
- KREMEN1 | c.637G>A p.A213T (on ENST00000407188; = p.A215T on NM_032045.5) | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.147); catalogued as rs369566037; called by muse, mutect2, varscan2
- KRT33B | c.331G>C p.E111Q | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV52440502; called by muse, mutect2, varscan2
- L1TD1 | c.2568G>C p.L856F | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63133255; called by muse, mutect2, varscan2
- LAMB1 | c.5185C>G p.L1729V | Missense Mutation (SNP) | VAF 44/145 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52737262; called by muse, mutect2, varscan2
- LCLAT1 | c.532G>A p.D178N | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100092669, COSV58371296; called by muse, mutect2, varscan2
- LECT2 | c.8C>G p.S3C | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.436); catalogued as COSV50846816; called by muse, mutect2, varscan2
- LIAS | c.489G>C p.K163N (on ENST00000261434 / NM_001363700.2; = p.K266N on NM_006859.4) | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54695228; called by muse, mutect2, varscan2
- LIMD1 | c.887C>T p.S296F | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.033); catalogued as COSV56266329; called by muse, mutect2
- LINGO3 | c.1539G>C p.E513D | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV68261088; called by muse, varscan2
- LMTK2 | c.557G>A p.G186E | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs1352693997, COSV51992563; called by muse, mutect2
- LRRC57 | c.222G>T p.L74= | Splice Region (SNP) | VAF 14/55 reads (25%) | catalogued as COSV52999316; called by muse, mutect2, varscan2
- LSM3 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 33/195 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV53204113; called by muse, mutect2, varscan2
- MACF1 | c.16093G>C p.E5365Q (on ENST00000372915; = p.E3298Q on NM_012090.5) | Missense Mutation (SNP) | VAF 25/64 reads (39%) | catalogued as COSV57112086; called by muse, mutect2, varscan2
- MANSC1 | c.1204G>A p.V402I | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.29); PolyPhen benign (0.068); catalogued as rs138511907; called by muse, mutect2, varscan2
- MAP3K7 | c.1672G>A p.E558K (on ENST00000369329 / NM_145331.3; = p.E531K on NM_003188.4) | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.344); catalogued as COSV65223852; called by muse, mutect2, varscan2
- MAP4K2 | c.2108C>T p.S703L | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs926682182, COSV53641492; called by muse, mutect2, varscan2
- MAPK10 | c.176G>T p.R59I (on ENST00000359221 / NM_001351625.2; = p.R97I on NM_002753.5) | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV60378353; called by muse, mutect2, varscan2
- MAPK15 | c.1031T>C p.L344P | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as rs782644613, COSV62027696; called by muse, mutect2, varscan2
- MARCO | c.197A>C p.Q66P | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.367); catalogued as COSV100503670; called by muse, mutect2
- MAST1 | c.3515C>T p.S1172L | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.306); catalogued as rs1272427169, COSV99263357; called by muse, mutect2, varscan2
- MBTPS1 | c.355G>C p.D119H | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.428); catalogued as rs1567500405, COSV58569912; called by muse, mutect2, varscan2
- MCTP1 | c.2293G>C p.E765Q | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.94); catalogued as COSV56508041; called by muse, mutect2, varscan2
- MDGA1 | c.431G>A p.R144Q | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV51799188; called by muse, mutect2
- MED12 | c.3205G>T p.D1069Y | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.834); catalogued as COSV61334900, COSV99048825; called by muse, mutect2, varscan2
- MED13L | c.1204G>C p.E402Q | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.14); catalogued as COSV56117402; called by muse, mutect2, varscan2
- MEP1A | c.1540G>A p.E514K | Missense Mutation (SNP) | VAF 20/135 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.627); catalogued as COSV57918901; called by muse, mutect2, varscan2
- MGARP | c.556G>C p.E186Q | Missense Mutation (SNP) | VAF 48/237 reads (20%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.858); catalogued as COSV67449147; called by muse, mutect2, varscan2
- MIA2 | c.1196A>T p.K399I | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV54490644; called by muse, mutect2
- MIA2 | c.1197A>T p.K399N | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54490679; called by muse, mutect2
- MICAL1 | c.1821C>A p.F607L | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.21); catalogued as rs759102155, COSV57804545; called by muse, mutect2, varscan2
- MICAL1 | c.1481A>G p.N494S | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs146727348; called by muse, mutect2, varscan2
- MMRN1 | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.34); catalogued as COSV53335101; called by muse, mutect2, varscan2
- MOAP1 | c.535G>A p.E179K | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); catalogued as COSV52092306, COSV52092683; called by muse, mutect2, varscan2
- MOXD1 | c.1117C>G p.L373V | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV60942549; called by muse, mutect2, varscan2
- MRS2 | c.372G>C p.M124I | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0.111); catalogued as COSV51234090; called by muse, mutect2, varscan2
- MRTFA | c.761C>G p.S254C | Missense Mutation (SNP) | VAF 67/165 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.312); catalogued as COSV62932179; called by muse, mutect2, varscan2
- MRTO4 | c.682G>C p.E228Q | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.229); catalogued as COSV57673302; called by muse, mutect2, varscan2
- MUC1 | c.3431C>G p.S1144* (on ENST00000611571 / NM_001371720.1; = p.S155* on NM_002456.6 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 20/72 reads (28%) | catalogued as COSV100104629; called by muse, mutect2, varscan2
- MUC17 | c.8830G>C p.E2944Q | Missense Mutation (SNP) | VAF 39/217 reads (18%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.727); catalogued as COSV60283186; called by muse, mutect2, varscan2
- MYCBP2 | c.12113G>T p.S4038I (on ENST00000357337; = p.S4076I on NM_015057.5) | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV62012962; called by muse, mutect2, varscan2
- MYH9 | c.5278G>T p.D1760Y | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV53383539; called by muse, mutect2, varscan2
- MYO9A | c.4931G>C p.R1644T | Missense Mutation (SNP) | VAF 27/106 reads (25%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as COSV61848809; called by muse, mutect2, varscan2
- MYOM1 | c.1132G>A p.E378K | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.05); catalogued as rs1257258501, COSV55287584; called by muse, mutect2
- NAA16 | c.405G>C p.E135D | Missense Mutation (SNP) | VAF 6/118 reads (5%) | SIFT tolerated (0.63); PolyPhen benign (0.048); catalogued as COSV65064648; called by muse, mutect2
- NAALADL1 | c.737G>A p.R246Q | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs752886257, COSV60523012; called by muse, mutect2, varscan2
- NCBP2 | c.249C>G p.F83L | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58317282; called by muse, mutect2, varscan2
- NEB | c.8845C>G p.L2949V | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.23); PolyPhen benign (0.034); catalogued as COSV50863375; called by muse, mutect2, varscan2
- NELL2 | c.1672G>T p.E558* | Nonsense Mutation (SNP) | VAF 15/76 reads (20%) | catalogued as COSV100420242; called by muse, mutect2, varscan2
- NEXMIF | c.2376C>A p.C792* | Nonsense Mutation (SNP) | VAF 29/122 reads (24%) | catalogued as COSV99281339; called by muse, mutect2, varscan2
- NFATC3 | c.2851C>T p.P951S | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.996); catalogued as COSV60471977; called by muse, mutect2, varscan2
- NFE2L3 | c.670C>T p.Q224* | Nonsense Mutation (SNP) | VAF 13/40 reads (33%) | catalogued as rs757931657, COSV99283892; called by muse, mutect2, varscan2
- NLGN3 | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100704838, COSV62442137; called by muse, mutect2, varscan2
- NLRP3 | c.1222T>G p.F408V | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as COSV60221612; called by muse, mutect2
- NMT2 | c.141G>C p.K47N | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.632); catalogued as COSV65383631; called by muse, mutect2, varscan2
- NOC3L | c.2004G>C p.Q668H | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.062); catalogued as COSV64929716; called by muse, mutect2, varscan2
- NPAP1 | c.1356G>T p.E452D | Missense Mutation (SNP) | VAF 8/97 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0.01); catalogued as COSV61505413, COSV61510892; called by muse, mutect2
- NPR3 | c.1310G>A p.G437E | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779492545, COSV54085581; called by muse, mutect2, varscan2
- NRAP | c.1023G>A p.M341I | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.952); catalogued as COSV63489193; called by muse, mutect2, varscan2
- NRBP1 | c.706G>C p.E236Q | Missense Mutation (SNP) | VAF 20/120 reads (17%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.566); catalogued as COSV51993544; called by muse, mutect2, varscan2
- NRBP2 | c.1165C>T p.R389* | Nonsense Mutation (SNP) | VAF 17/38 reads (45%) | catalogued as rs1554652036, COSV100589229; called by muse, mutect2, varscan2
- NTSR2 | c.1145C>A p.P382H | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as COSV60990711; called by muse, mutect2, varscan2
- NUP160 | c.2686C>G p.Q896E | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV65853867, COSV65854463; called by muse, mutect2, varscan2
- NUP214 | c.2320G>C p.E774Q | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1471335381, COSV63908348; called by muse, mutect2, varscan2
- NXNL2 | c.212C>G p.S71* | Nonsense Mutation (SNP) | VAF 6/23 reads (26%) | catalogued as rs1389388551, COSV101018356; called by muse, mutect2, varscan2
- NYNRIN | c.1016C>T p.S339L | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.115); catalogued as COSV101230648; called by muse, mutect2
- NYNRIN | c.1189C>G p.L397V | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.001); catalogued as COSV66841585; called by muse, mutect2, varscan2
- OR10AG1 | c.308G>C p.C103S | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.282); catalogued as COSV56632096; called by muse, mutect2, varscan2
- OR10J3 | c.218G>A p.C73Y | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as rs756979181, COSV59953876; called by muse, mutect2, varscan2
- OR14K1 | c.479G>T p.G160V | Missense Mutation (SNP) | VAF 56/150 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.405); catalogued as COSV51720761, COSV99315134; called by muse, mutect2, varscan2
- OR2M2 | c.992C>T p.S331F | Missense Mutation (SNP) | VAF 40/123 reads (33%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); catalogued as COSV62897982, COSV62898109; called by muse, mutect2, varscan2
- OR4A47 | c.469C>T p.Q157* | Nonsense Mutation (SNP) | VAF 28/133 reads (21%) | catalogued as COSV71444936; called by muse, mutect2, varscan2
- OR4C46 | c.393G>C p.M131I | Missense Mutation (SNP) | VAF 46/122 reads (38%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as COSV100060615, COSV60218641; called by muse, mutect2, varscan2
- OR4D11 | c.911G>C p.R304T | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.073); catalogued as COSV100506602; called by muse, mutect2
- OR51I1 | c.781T>G p.S261A | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.987); catalogued as COSV66507495; called by muse, mutect2, varscan2
- OR56A4 | c.441C>G p.I147M | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.477); catalogued as COSV58109627; called by muse, mutect2, varscan2
- OR6K6 | c.149G>A p.R50K (on ENST00000368144; = p.R26K on NM_001005184.1) | Missense Mutation (SNP) | VAF 33/181 reads (18%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV63743756, COSV63743879; called by muse, mutect2, varscan2
- OR6K6 | c.962A>C p.N321T (on ENST00000368144; = p.N297T on NM_001005184.1) | Missense Mutation (SNP) | VAF 12/175 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63743765; called by muse, mutect2
- OR6N1 | c.391C>T p.H131Y | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.652); catalogued as rs375461321; called by muse, mutect2, varscan2
- OSBPL2 | c.1118C>G p.S373C (on ENST00000313733 / NM_144498.4; = p.S361C on NM_014835.4) | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV58215780; called by muse, mutect2, varscan2
- OSBPL3 | c.53C>G p.S18* | Nonsense Mutation (SNP) | VAF 13/70 reads (19%) | catalogued as COSV100514369; called by muse, mutect2, varscan2
- OSTM1 | c.709G>T p.E237* | Nonsense Mutation (SNP) | VAF 16/69 reads (23%) | catalogued as COSV51969909, COSV99514243; called by muse, mutect2, varscan2
- OVCH1 | c.2396G>C p.R799T | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV58960804; called by muse, mutect2, varscan2
- P2RY12 | c.88C>G p.L30V | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV56372637; called by muse, mutect2, varscan2
- PACSIN3 | c.307C>T p.Q103* | Nonsense Mutation (SNP) | VAF 19/50 reads (38%) | catalogued as rs1295006096, COSV100096487, COSV54066486; called by muse, mutect2, varscan2
- PALMD | c.1345G>A p.D449N | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV54163459; called by muse, mutect2, varscan2
- PCDH9 | c.3666T>G p.Y1222* (on ENST00000377865 / NM_203487.3; = p.Y1188* on NM_020403.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 5/46 reads (11%) | catalogued as COSV100122312; called by muse, varscan2
- PCDHA2 | c.1246G>T p.E416* | Nonsense Mutation (SNP) | VAF 33/120 reads (28%) | catalogued as rs782513202, COSV100974059, COSV65364919; called by muse, mutect2, varscan2
- PCDHB11 | c.671G>C p.G224A | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV53375853, COSV53376655; called by muse, mutect2, varscan2
- PCDHB7 | c.2023G>C p.E675Q | Missense Mutation (SNP) | VAF 26/210 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.756); catalogued as COSV50757471; called by muse, mutect2, varscan2
- PCIF1 | c.862C>T p.L288F | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV65026190; called by muse, mutect2
- PCNX4 | c.2098G>C p.D700H (on ENST00000406854 / NM_001330177.2; = p.D466H on NM_022495.5) | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58302881; called by muse, varscan2
- PDE1C | c.274G>A p.D92N | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV58507035; called by muse, mutect2, varscan2
- PDGFRA | c.1751C>G p.S584* | Nonsense Mutation (SNP) | VAF 35/72 reads (49%) | catalogued as COSV99957070, COSV99957222; called by muse, mutect2, varscan2
- PFN2 | c.413C>G p.S138C | Missense Mutation (SNP) | VAF 53/343 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.62); catalogued as COSV53523040; called by muse, mutect2, varscan2
- PGAM2 | c.37G>A p.E13K | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.258); catalogued as rs1026868358, COSV51977408; called by muse, mutect2, varscan2
- PHKA2 | c.3052G>A p.E1018K | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.81); PolyPhen benign (0.003); catalogued as COSV66052921; called by muse, mutect2, varscan2
- PIP5K1A | c.1570G>A p.E524K (on ENST00000368888 / NM_001135638.2; = p.E511K on NM_003557.3) | Missense Mutation (SNP) | VAF 56/212 reads (26%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.114); catalogued as COSV62957740; called by muse, mutect2, varscan2
- PIPOX | c.19C>A p.L7I | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.025); catalogued as COSV60141268; called by muse, mutect2
- PJA2 | c.1714C>G p.Q572E | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); catalogued as COSV63272187; called by muse, mutect2, varscan2
- PKD1L1 | c.4204C>G p.Q1402E | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.169); catalogued as rs749103059, COSV56963248; called by muse, mutect2
- PKDREJ | c.4601T>A p.L1534H | Missense Mutation (SNP) | VAF 41/261 reads (16%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV53547477; called by muse, mutect2, varscan2
- PKHD1L1 | c.7777G>A p.D2593N | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.248); catalogued as COSV65737548, COSV65748073; called by muse, mutect2, varscan2
- PKNOX1 | c.766G>A p.D256N | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.135); catalogued as COSV52334854; called by muse, mutect2, varscan2
- PLA2G1B | c.369C>A p.N123K | Missense Mutation (SNP) | VAF 47/168 reads (28%) | SIFT tolerated (0.59); PolyPhen benign (0.005); catalogued as rs199972494, COSV100387519, COSV57679230; called by muse, mutect2, varscan2
- PLA2R1 | c.1600C>T p.R534* | Nonsense Mutation (SNP) | VAF 13/62 reads (21%) | catalogued as rs748435935, COSV51775026; called by muse, mutect2, varscan2
- PLB1 | c.1592C>T p.T531I | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.021); catalogued as rs1199559332, COSV59821383; called by muse, mutect2, varscan2
- PLCXD3 | c.292C>T p.R98* | Nonsense Mutation (SNP) | VAF 24/89 reads (27%) | catalogued as rs749287158, COSV60606708; called by muse, mutect2, varscan2
- PLK3 | c.1267G>A p.E423K | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT tolerated (0.42); PolyPhen benign (0.109); catalogued as COSV59499376; called by muse, mutect2, varscan2
- PLP2 | c.74G>A p.G25E | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV66239443; called by muse, mutect2
- PLXNA1 | c.986G>A p.G329D | Missense Mutation (SNP) | VAF 25/113 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV52523567; called by muse, mutect2, varscan2
- PLXNA4 | c.4555A>G p.I1519V | Missense Mutation (SNP) | VAF 45/231 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV58113236; called by muse, mutect2, varscan2
- PNLDC1 | c.144G>C p.Q48H | Missense Mutation (SNP) | VAF 30/213 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.012); catalogued as COSV51704242; called by muse, mutect2, varscan2
- POLR1C | c.873G>C p.E291D | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT tolerated (0.86); PolyPhen benign (0.009); catalogued as COSV54828422; called by muse, mutect2, varscan2
- POLR3C | c.110G>C p.R37T | Missense Mutation (SNP) | VAF 50/135 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.946); catalogued as COSV61936197; called by muse, mutect2, varscan2
- POM121 | c.2215G>C p.E739Q (on ENST00000434423; = p.E474Q on NM_172020.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.648); catalogued as COSV57513114; called by muse, mutect2, varscan2
- PPFIA2 | c.3074G>C p.G1025A | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV61024841, COSV61060168; called by muse, mutect2, varscan2
- PPFIBP2 | c.1173G>C p.L391F | Missense Mutation (SNP) | VAF 21/117 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as rs1383088345, COSV55075359; called by muse, mutect2, varscan2
- PPP1R15B | c.171G>C p.E57D | Missense Mutation (SNP) | VAF 23/122 reads (19%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.073); catalogued as COSV65815475; called by muse, mutect2, varscan2
- PPP1R16A | c.404G>C p.S135T | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.326); catalogued as COSV52952580; called by muse, mutect2, varscan2
- PPP1R21 | c.304C>G p.Q102E | Missense Mutation (SNP) | VAF 14/163 reads (9%) | SIFT tolerated (1); PolyPhen probably damaging (0.987); catalogued as COSV54282936; called by muse, mutect2
- PPP2R1B | c.58G>C p.D20H | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs201793048, COSV59535022; called by muse, mutect2, varscan2
- PRB1 | c.787C>T p.P263S | Missense Mutation (SNP) | VAF 28/156 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.014); catalogued as rs781440647, COSV53702917; called by muse, mutect2, varscan2
- PRDM13 | c.335C>G p.S112C | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV65029148; called by muse, mutect2, varscan2
- PRDM4 | c.844G>C p.D282H | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.135); catalogued as COSV57304976; called by muse, mutect2, varscan2
- PRDM7 | c.609C>T p.L203= | Splice Region (SNP) | VAF 24/116 reads (21%) | catalogued as COSV57986286; called by muse, mutect2, varscan2
- PRKCD | c.1117G>C p.E373Q | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.65); PolyPhen benign (0.011); catalogued as rs782345985, COSV57847203; called by muse, mutect2, varscan2
- PRKCD | c.1216G>A p.E406K | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT tolerated (0.58); PolyPhen benign (0.007); catalogued as rs1553669067, COSV57847249; called by muse, mutect2, varscan2
- PRSS35 | c.647G>C p.R216T | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV63800282, COSV63800450; called by muse, varscan2
- PRSS35 | c.730G>A p.E244K | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.43); PolyPhen benign (0.015); catalogued as rs541411659, COSV63800286; called by muse, varscan2
- PTGFR | c.604C>G p.L202V | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT tolerated (0.98); PolyPhen benign (0.125); catalogued as COSV66114650; called by muse, mutect2, varscan2
- PTPN6 | c.19C>T p.R7* | Nonsense Mutation (SNP) | VAF 10/60 reads (17%) | catalogued as COSV59684096; called by muse, mutect2, varscan2
- PTPRC | c.1219C>G p.Q407E | Missense Mutation (SNP) | VAF 34/136 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV61408370; called by muse, mutect2, varscan2
- PTPRD | c.1473A>C p.K491N | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV61933996; called by mutect2, varscan2
- PTPRF | c.4307G>A p.R1436K | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63443689; called by muse, varscan2
- PTPRS | c.5058G>A p.R1686= | Splice Region (SNP) | VAF 8/48 reads (17%) | catalogued as COSV53613871; called by muse, mutect2, varscan2
- PUM1 | c.914C>G p.S305C | Missense Mutation (SNP) | VAF 43/150 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV57083139, COSV57088334; called by muse, mutect2, varscan2
- QKI | c.861_863del p.Y288del | In Frame Del (DEL) | VAF 23/117 reads (20%) | catalogued as COSV51690940; called by mutect2, pindel, varscan2
- RAB1A | c.36C>G p.F12L | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.424); catalogued as COSV99573532; called by muse, mutect2
- RAB33A | c.670G>C p.E224Q | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV57061357, COSV99924726; called by muse, mutect2, varscan2
- RAB36 | c.435G>C p.K145N | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV54074327, COSV99572125; called by muse, mutect2, varscan2
- RBAK | c.1129G>A p.E377K | Missense Mutation (SNP) | VAF 50/117 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs1456489524, COSV62330894; called by muse, mutect2, varscan2
- RCVRN | c.506A>T p.E169V | Missense Mutation (SNP) | VAF 21/134 reads (16%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.999); catalogued as COSV56841195; called by muse, mutect2, varscan2
- REV1 | c.3499G>C p.D1167H | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51482897; called by muse, mutect2, varscan2
- REXO4 | c.531G>T p.K177N | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.201); catalogued as COSV64241330; called by muse, mutect2, varscan2
- RFC4 | c.854C>G p.S285C | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV56216223; called by muse, mutect2, varscan2
- RHOBTB1 | c.281G>A p.R94H | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs774295991, COSV61958080; called by muse, mutect2, varscan2
- RILPL2 | c.530G>A p.R177K | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (0.96); PolyPhen benign (0.294); catalogued as COSV54912143; called by muse, varscan2
- RIMS1 | c.3724C>A p.P1242T | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as COSV53445957; called by mutect2, varscan2
- RNF168 | c.1541C>G p.S514* | Nonsense Mutation (SNP) | VAF 154/349 reads (44%) | catalogued as COSV100535046; called by muse, mutect2, varscan2
- ROBO2 | c.2906C>T p.S969L | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.554); catalogued as COSV59902569; called by muse, mutect2
- ROCK2 | c.277G>A p.D93N | Missense Mutation (SNP) | VAF 28/155 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as COSV55077004; called by muse, mutect2, varscan2
- RP1 | c.1721C>G p.S574* | Nonsense Mutation (SNP) | VAF 10/77 reads (13%) | catalogued as COSV99608294; called by muse, mutect2, varscan2
- RPL7 | c.413C>T p.P138L | Missense Mutation (SNP) | VAF 19/111 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.658); catalogued as COSV53581708; called by muse, mutect2, varscan2
- RPS6KA3 | c.880G>A p.E294K | Missense Mutation (SNP) | VAF 44/146 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.391); catalogued as COSV65387236; called by muse, mutect2, varscan2
- RPSA | c.767C>T p.S256F | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.54); catalogued as rs1265647940, COSV57191156; called by muse, mutect2, varscan2
- RSPH10B2 | c.115G>C p.E39Q | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.143); catalogued as COSV99786270; called by mutect2, varscan2
- RTL10 | c.45C>G p.I15M | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.923); catalogued as COSV100144235, COSV60735502; called by muse, mutect2, varscan2
- RUBCNL | c.755C>G p.S252C | Missense Mutation (SNP) | VAF 50/124 reads (40%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.628); catalogued as COSV59786553; called by muse, mutect2, varscan2
- RUSC1 | c.235C>T p.P79S | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.009); catalogued as COSV52738789; called by muse, mutect2, varscan2
- RWDD4 | c.92C>G p.S31C | Missense Mutation (SNP) | VAF 27/124 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.018); catalogued as COSV100419101, COSV58215360; called by muse, mutect2, varscan2
- SALL1 | c.1543G>C p.E515Q | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as CM054106, COSV51754937; called by muse, mutect2, varscan2
- SAMD9 | c.4155G>T p.K1385N | Missense Mutation (SNP) | VAF 45/93 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV66073746; called by muse, mutect2, varscan2
- SBNO1 | c.718G>C p.E240Q (on ENST00000420886; = p.E239Q on NM_018183.5) | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as COSV57339869; called by muse, mutect2, varscan2
- SCG2 | c.1462G>C p.E488Q | Missense Mutation (SNP) | VAF 13/108 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.908); catalogued as COSV59539380; called by muse, mutect2, varscan2
- SCN10A | c.3253G>T p.E1085* | Nonsense Mutation (SNP) | VAF 3/18 reads (17%) | catalogued as COSV101479477, COSV71861467; called by muse, mutect2
- SDC2 | c.392A>G p.Y131C | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.563); catalogued as rs952503590, COSV56226562; called by muse, mutect2, varscan2
- SELENOO | c.970G>A p.E324K | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT tolerated (0.75); PolyPhen benign (0.019); catalogued as rs747525320, COSV66598741; called by muse, mutect2, varscan2
- SEPTIN9 | c.1576G>C p.E526Q (on ENST00000427177 / NM_001113491.2; = p.E508Q on NM_006640.4) | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as COSV61202344, COSV61203068; called by muse, mutect2
- SERPINI2 | c.233A>C p.Q78P | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.017); catalogued as COSV52985060; called by muse, mutect2, varscan2
- SESN3 | c.1252G>C p.D418H | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99565832; called by muse, mutect2
- SGO2 | c.2335G>T p.D779Y | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV63414488; called by muse, mutect2, varscan2
- SINHCAF | c.602C>T p.A201V | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.012); catalogued as COSV61797100; called by muse, mutect2, varscan2
- SIPA1L1 | c.2932G>A p.E978K | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV62169155; called by muse, mutect2, varscan2
- SLC17A7 | c.1579G>A p.E527K | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV55546969; called by muse, mutect2, varscan2
- SLC24A3 | c.1294G>C p.E432Q | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0.017); catalogued as COSV60115083; called by muse, mutect2, varscan2
- SLC29A4 | c.713C>T p.S238L | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs991980673, COSV51873338; called by muse, mutect2, varscan2
- SLC4A5 | c.1186G>A p.E396K | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs145653085; called by muse, mutect2, varscan2
- SLC52A2 | c.894G>C p.Q298H | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV57351222; called by muse, mutect2, varscan2
- SLC6A20 | c.919G>A p.E307K | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.825); catalogued as rs866708210, COSV62070600; called by muse, mutect2, varscan2
- SLC6A9 | c.332T>C p.L111P (on ENST00000360584 / NM_201649.4; = p.L57P on NM_006934.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62210061, COSV62210118; called by muse, mutect2, varscan2
- SLCO1B3 | c.1927T>A p.F643I | Missense Mutation (SNP) | VAF 5/92 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV99681937; called by muse, mutect2
- SLCO4C1 | c.250G>C p.E84Q | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT tolerated (0.17); PolyPhen benign (0.022); catalogued as COSV60513834, COSV60518009; called by muse, mutect2, varscan2
- SLITRK3 | c.2221G>A p.E741K | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV53846573; called by muse, mutect2, varscan2
- SLX4IP | c.409G>C p.E137Q | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.04); catalogued as COSV100570678; called by muse, mutect2
- SMG1 | c.3348G>A p.G1116= | Splice Region (SNP) | VAF 25/93 reads (27%) | catalogued as COSV67170092; called by muse, mutect2, varscan2
- SMG5 | c.724G>C p.E242Q | Missense Mutation (SNP) | VAF 82/180 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.425); catalogued as COSV62434494; called by muse, mutect2, varscan2
- SNAI2 | c.625+2T>A p.X209_splice | Splice Site (SNP) | VAF 35/96 reads (36%) | catalogued as COSV50078715; called by muse, mutect2, varscan2
- SNX1 | c.1546C>A p.P516T | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56037755; called by muse, mutect2, varscan2
- SNX31 | c.997G>A p.D333N | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as rs776282912, COSV61262317; called by muse, varscan2
- SOS1 | c.1651G>A p.E551K | Missense Mutation (SNP) | VAF 48/112 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); catalogued as COSV67674367; called by muse, mutect2, varscan2
- SOS1 | c.1474G>C p.E492Q | Missense Mutation (SNP) | VAF 52/106 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67674373, COSV67674970; called by muse, mutect2, varscan2
- SPATA17 | c.1043C>G p.S348* | Nonsense Mutation (SNP) | VAF 86/289 reads (30%) | catalogued as COSV100861217, COSV65121916; called by muse, mutect2, varscan2
- SPICE1 | c.219G>C p.L73F | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55619249; called by muse, mutect2
- SPINK8 | c.132G>C p.K44N | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.017); catalogued as COSV71285441; called by muse, mutect2, varscan2
- SPTA1 | c.7009G>C p.E2337Q | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV63750557; called by muse, mutect2, varscan2
- SRCIN1 | c.163C>G p.R55G | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1306885491; called by muse, mutect2, varscan2
- SREK1 | c.57G>C p.L19F | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.326); catalogued as COSV52332087; called by muse, mutect2, varscan2
- ST6GAL1 | c.182A>T p.Q61L | Missense Mutation (SNP) | VAF 14/96 reads (15%) | PolyPhen benign (0.015); catalogued as COSV51467672; called by muse, mutect2, varscan2
- STRADA | c.238G>C p.E80Q (on ENST00000336174 / NM_001363786.1; = p.E43Q on NM_153335.6) | Missense Mutation (SNP) | VAF 26/130 reads (20%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.673); catalogued as COSV55561977; called by muse, mutect2, varscan2
- SULT1C2 | c.664G>C p.D222H | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV52264216; called by muse, mutect2, varscan2
- SYNE1 | c.2351A>T p.E784V (on ENST00000367255 / NM_182961.4; = p.E791V on NM_033071.3) | Missense Mutation (SNP) | VAF 27/114 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.179); catalogued as COSV54933799; called by muse, mutect2, varscan2
- SYNJ1 | c.4750C>G p.L1584V | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as COSV59145909; called by muse, mutect2, varscan2
- SYNJ1 | c.3847C>G p.Q1283E | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.972); catalogued as COSV100449497; called by muse, mutect2
- TAF7 | c.669C>G p.F223L | Missense Mutation (SNP) | VAF 43/92 reads (47%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.97); catalogued as COSV57664955; called by muse, mutect2, varscan2
- TARDBP | c.272C>A p.S91* | Nonsense Mutation (SNP) | VAF 25/89 reads (28%) | catalogued as COSV53570807, COSV99534383; called by muse, mutect2, varscan2
- TASOR2 | c.5203G>C p.D1735H | Missense Mutation (SNP) | VAF 25/47 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.259); catalogued as COSV60166324; called by muse, mutect2, varscan2
- TBATA | c.151C>T p.R51W | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.292); catalogued as rs199669673, COSV54717710, COSV54717737; called by muse, mutect2, varscan2
- TBC1D1 | c.2365G>C p.D789H | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV54715966; called by muse, mutect2, varscan2
- TBC1D5 | c.1429A>T p.S477C | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.514); catalogued as COSV53752381; called by muse, mutect2, varscan2
- TBC1D8B | c.65C>T p.S22F | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as rs993026864, COSV52176981; called by muse, mutect2, varscan2
- TBC1D8B | c.403G>C p.D135H | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.013); catalogued as COSV52177005; called by muse, mutect2, varscan2
- TBC1D8B | c.2969C>G p.S990C | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.613); catalogued as COSV52177030; called by muse, mutect2, varscan2
- TBCD | c.3177C>G p.F1059L | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.046); catalogued as COSV62798779; called by muse, mutect2, varscan2
- TBCK | c.804G>A p.M268I (on ENST00000273980 / NM_001163436.4; = p.M205I on NM_033115.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV56753310; called by muse, mutect2, varscan2
- TCTN1 | c.852C>G p.I284M (on ENST00000551590 / NM_001173975.3; = p.I270M on NM_024549.6) | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.422); catalogued as COSV66540669; called by muse, mutect2, varscan2
- TECR | c.13G>A p.E5K | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.021); catalogued as COSV53110127; called by muse, mutect2, varscan2
- TENM2 | c.4146G>C p.Q1382H (on ENST00000518659 / NM_001122679.2; = p.Q1143H on NM_001080428.3) | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.905); catalogued as COSV69125197; called by muse, mutect2, varscan2
- TEX11 | c.1510G>C p.E504Q (on ENST00000344304; = p.E489Q on NM_031276.3) | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.831); catalogued as rs1483378881, COSV60227962; called by muse, mutect2, varscan2
- THOC2 | c.3242G>T p.G1081V | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT tolerated (0.55); PolyPhen benign (0.155); catalogued as COSV55542567; called by muse, mutect2, varscan2
- THSD7B | c.388G>C p.E130Q | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.062); catalogued as COSV55665973, COSV55731772; called by muse, mutect2, varscan2
- TIAL1 | c.454G>T p.E152* | Nonsense Mutation (SNP) | VAF 17/47 reads (36%) | catalogued as COSV100958365; called by muse, mutect2, varscan2
- TLNRD1 | c.269C>G p.S90C | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as COSV99146139; called by muse, mutect2
- TLR10 | c.814G>C p.E272Q | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.132); catalogued as rs1320211369, COSV58299500; called by muse, mutect2, varscan2
- TLR8 | c.1367C>G p.S456* (on ENST00000218032 / NM_138636.5; = p.S474* on NM_016610.4) | Nonsense Mutation (SNP) | VAF 53/149 reads (36%) | catalogued as COSV99486831, COSV99487170; called by muse, mutect2, varscan2
- TM4SF4 | c.595G>C p.D199H | Missense Mutation (SNP) | VAF 27/123 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.127); catalogued as COSV59515330; called by muse, mutect2, varscan2
- TMEM241 | c.316G>C p.E106Q | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.735); catalogued as COSV67243420; called by muse, mutect2, varscan2
- TMEM38A | c.695C>G p.S232* | Nonsense Mutation (SNP) | VAF 50/338 reads (15%) | catalogued as rs1373451060, COSV99495417; called by muse, mutect2, varscan2
- TMEM81 | c.464C>G p.S155C | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV52703322; called by muse, mutect2, varscan2
- TNRC18 | c.3298C>T p.Q1100* | Nonsense Mutation (SNP) | VAF 4/10 reads (40%) | catalogued as rs1432597102, COSV101269795; called by muse, mutect2, varscan2
- TNS4 | c.1673-1G>A p.X558_splice | Splice Site (SNP) | VAF 7/33 reads (21%) | catalogued as COSV54183967; called by muse, mutect2, varscan2
- TRAPPC4 | c.363C>G p.I121M | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.916); catalogued as COSV57722133, COSV57722348; called by muse, mutect2, varscan2
- TRIM33 | c.1732G>C p.G578R | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.095); catalogued as COSV61821446; called by muse, mutect2, varscan2
- TRMT1 | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 49/103 reads (48%) | SIFT tolerated (0.17); PolyPhen benign (0.153); catalogued as COSV52834161; called by muse, mutect2, varscan2
- TRMT112 | c.273G>A p.V91= | Splice Region (SNP) | VAF 14/58 reads (24%) | catalogued as rs1259026860, COSV50004951; called by muse, mutect2, varscan2
- TRMT12 | c.328G>C p.E110Q | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT tolerated (0.26); PolyPhen benign (0.01); catalogued as COSV60776682; called by muse, mutect2, varscan2
- TRMT2A | c.1759G>C p.E587Q | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.823); catalogued as COSV52812757; called by muse, mutect2, varscan2
- TRPM3 | c.373G>C p.E125Q (on ENST00000357533 / NM_001366142.2; = p.E94Q on NM_001007471.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.709); catalogued as rs759169807, COSV62468265; called by muse, mutect2, varscan2
- TSKU | c.730G>A p.E244K | Missense Mutation (SNP) | VAF 31/114 reads (27%) | SIFT tolerated (0.56); PolyPhen benign (0.119); catalogued as COSV60751109; called by muse, mutect2, varscan2
- TTC3 | c.3166C>T p.H1056Y | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.133); catalogued as COSV61287765; called by muse, mutect2
- TTN | c.102314C>T p.S34105L (on ENST00000591111; = p.S26681L on NM_003319.4) | Missense Mutation (SNP) | VAF 7/39 reads (18%) | PolyPhen possibly damaging (0.843); catalogued as COSV59945000; called by muse, mutect2, varscan2
- TTN | c.37529A>G p.Q12510R (on ENST00000591111; = p.Q5086R on NM_003319.4) | Missense Mutation (SNP) | VAF 30/83 reads (36%) | PolyPhen possibly damaging (0.644); catalogued as COSV59945060; called by muse, mutect2, varscan2
- TTN | c.20532A>T p.R6844S (on ENST00000591111; = p.R5917S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/29 reads (17%) | PolyPhen benign (0.013); catalogued as rs1366700015, COSV100622125; called by muse, mutect2
- TTN | c.6489C>A p.H2163Q (on ENST00000591111; = p.H2117Q on NM_003319.4) | Missense Mutation (SNP) | VAF 9/76 reads (12%) | PolyPhen probably damaging (0.998); catalogued as COSV59945091; called by muse, mutect2, varscan2
- TUBA3E | c.283G>A p.G95R | Missense Mutation (SNP) | VAF 10/119 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1193502371, COSV56058671; called by muse, mutect2
- TXN2 | c.306G>C p.K102N | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.223); catalogued as COSV53397202; called by muse, mutect2, varscan2
- UBE2H | c.196C>A p.P66T | Missense Mutation (SNP) | VAF 23/146 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs1470710408, COSV62920131; called by muse, mutect2, varscan2
- UBE2U | c.366G>C p.E122D | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.14); catalogued as COSV64280596, COSV64281587; called by muse, mutect2, varscan2
- UGT1A1 | c.477C>G p.I159M | Missense Mutation (SNP) | VAF 27/138 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs199766420, COSV59384447, COSV59384622; called by muse, mutect2, varscan2
- UMODL1 | c.1520-1G>A p.X507_splice | Splice Site (SNP) | VAF 16/92 reads (17%) | catalogued as COSV61159573; called by muse, mutect2, varscan2
- UNC5C | c.695C>G p.S232C | Missense Mutation (SNP) | VAF 63/165 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs749118567, COSV71658745; called by muse, mutect2, varscan2
- UROC1 | c.1236G>C p.Q412H | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.45); PolyPhen benign (0.007); catalogued as COSV52030312, COSV52030901; called by muse, varscan2
- UROC1 | c.1183G>C p.E395Q | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.51); PolyPhen benign (0.01); catalogued as COSV52030916, COSV52036118; called by muse, varscan2
- USP37 | c.66G>T p.W22C | Missense Mutation (SNP) | VAF 34/171 reads (20%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV51442072; called by muse, mutect2, varscan2
- USP46 | c.596C>T p.S199F | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101484294; called by muse, mutect2
- USP47 | c.2017G>A p.E673K (on ENST00000399455 / NM_001372095.1; = p.E585K on NM_017944.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.447); catalogued as COSV60461950; called by muse, mutect2, varscan2
- VEGFA | c.166G>A p.E56K (on ENST00000523873 / NM_001171623.1; = p.E236K on NM_003376.6) | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV57877981; called by muse, mutect2, varscan2
- VIT | c.1306G>C p.E436Q (on ENST00000389975 / NM_001177969.1; = p.E451Q on NM_053276.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 45/97 reads (46%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.954); catalogued as COSV64895728, COSV64898652; called by muse, mutect2, varscan2
- VNN2 | c.1057G>A p.E353K | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as rs1159729318, COSV58471904; called by muse, mutect2, varscan2
- VPS50 | c.2585G>A p.G862E | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59917001; called by muse, mutect2, varscan2
- WFDC6 | c.76G>C p.E26Q | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.249); catalogued as rs1167306698, COSV60548172; called by muse, mutect2, varscan2
- WNK1 | c.1021C>G p.R341G | Missense Mutation (SNP) | VAF 65/146 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60028063; called by muse, mutect2, varscan2
- XIRP2 | c.3205G>A p.E1069K (on ENST00000628543; = p.E1244K on NM_152381.6) | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99745479; called by muse, mutect2, varscan2
- XIRP2 | c.8253C>G p.F2751L (on ENST00000628543; = p.F2926L on NM_152381.6) | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1309957845, COSV54688742, COSV54719310, COSV99742302; called by muse, mutect2, varscan2
- ZAN | c.3991C>T p.Q1331* | Nonsense Mutation (SNP) | VAF 40/87 reads (46%) | catalogued as COSV100769986, COSV61810196; called by muse, mutect2, varscan2
- ZBP1 | c.1228G>C p.E410Q | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.886); catalogued as COSV59060871, COSV59061723, COSV59065049; called by muse, mutect2, varscan2
- ZBTB32 | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV52889582; called by muse, mutect2, varscan2
- ZBTB33 | c.232T>C p.F78L | Missense Mutation (SNP) | VAF 20/158 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV58533415; called by muse, mutect2, varscan2
- ZBTB4 | c.1909G>C p.E637Q | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT tolerated (0.29); PolyPhen benign (0.145); catalogued as COSV100263598; called by muse, mutect2, varscan2
- ZBTB7B | c.1111G>A p.E371K (on ENST00000292176; = p.E405K on NM_001252406.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52691596, COSV52691820; called by muse, mutect2, varscan2
- ZC3H7A | c.1553C>G p.S518* | Nonsense Mutation (SNP) | VAF 11/43 reads (26%) | catalogued as COSV100865565; called by mutect2, varscan2
- ZCCHC10 | c.303G>C p.K101N (on ENST00000509437 / NM_001300818.3; = p.K79N on NM_017665.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV60772519, COSV60772563, COSV60773001; called by muse, mutect2, varscan2
- ZCCHC13 | c.284G>C p.G95A | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as COSV59866049; called by muse, mutect2, varscan2
- ZEB1 | c.580G>A p.E194K | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV58035498, COSV58039665; called by muse, mutect2, varscan2
- ZEB2 | c.3280G>A p.E1094K | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.444); catalogued as COSV57953550, COSV57956836; called by muse, mutect2, varscan2
- ZFYVE9 | c.124C>A p.P42T | Missense Mutation (SNP) | VAF 30/126 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.172); catalogued as rs1192254529, COSV55091675; called by muse, mutect2, varscan2
- ZIC5 | c.1948G>C p.E650Q | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV57437087; called by muse, mutect2, varscan2
- ZNF107 | c.686C>T p.S229L | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as rs774039108, COSV61327443; called by muse, mutect2, varscan2
- ZNF107 | c.1190C>G p.S397* | Nonsense Mutation (SNP) | VAF 8/46 reads (17%) | catalogued as COSV100788445; called by muse, mutect2, varscan2
- ZNF14 | c.209G>C p.R70T | Missense Mutation (SNP) | VAF 40/111 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.111); catalogued as COSV59848737; called by muse, mutect2, varscan2
- ZNF146 | c.239C>T p.S80L | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.058); catalogued as COSV61931331, COSV61931416; called by muse, mutect2, varscan2
- ZNF155 | c.1420C>T p.H474Y | Missense Mutation (SNP) | VAF 59/156 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54206333, COSV54207766; called by muse, mutect2, varscan2
- ZNF157 | c.1278G>C p.K426N | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.041); catalogued as COSV65658620; called by muse, mutect2, varscan2
- ZNF250 | c.1408G>A p.E470K | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.253); catalogued as COSV52968536; called by muse, mutect2, varscan2
- ZNF254 | c.1323A>C p.K441N | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV61641514; called by muse, mutect2, varscan2
- ZNF254 | c.1913C>T p.A638V | Missense Mutation (SNP) | VAF 15/122 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.02); catalogued as COSV61641518; called by muse, varscan2
- ZNF44 | c.986A>G p.Y329C (on ENST00000356109 / NM_001164276.2; = p.Y281C on NM_016264.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 47/168 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61134915; called by muse, mutect2, varscan2
- ZNF471 | c.1009C>G p.Q337E | Missense Mutation (SNP) | VAF 21/146 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.209); catalogued as COSV57290439; called by muse, mutect2, varscan2
- ZNF534 | c.115G>C p.E39Q | Missense Mutation (SNP) | VAF 15/122 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56515327, COSV99989960; called by muse, mutect2, varscan2
- ZNF543 | c.1012C>T p.P338S | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV58626792; called by muse, mutect2, varscan2
- ZNF544 | c.1158del p.K387Nfs*93 | Frame Shift Del (DEL) | VAF 32/150 reads (21%) | catalogued as COSV99517272; called by mutect2, pindel, varscan2
- ZNF544 | c.1522G>C p.V508L | Missense Mutation (SNP) | VAF 38/192 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.028); catalogued as COSV54134912; called by muse, mutect2, varscan2
- ZNF550 | c.344C>G p.S115C | Missense Mutation (SNP) | VAF 89/358 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV57304121, COSV57307762; called by muse, mutect2, varscan2
- ZNF584 | c.305G>A p.R102K | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.62); PolyPhen benign (0.055); catalogued as COSV100183369; called by muse, mutect2
- ZNF606 | c.2157G>C p.E719D | Missense Mutation (SNP) | VAF 52/121 reads (43%) | SIFT tolerated (0.24); PolyPhen benign (0.071); catalogued as COSV58705372; called by muse, mutect2, varscan2
- ZNF639 | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 43/73 reads (59%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.775); catalogued as rs1157037304, COSV100418481, COSV58382845; called by muse, mutect2, varscan2
- ZNF675 | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.045); catalogued as COSV63095391; called by muse, mutect2, varscan2
- ZNF695 | c.727G>A p.E243K | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV60585087; called by muse, mutect2, varscan2
- ZNF773 | c.1177G>T p.G393W | Missense Mutation (SNP) | VAF 21/224 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56587968; called by muse, mutect2
- ZRANB3 | c.67G>C p.D23H | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as COSV51497425; called by muse, mutect2, varscan2
- ZSWIM1 | c.1033G>A p.E345K | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs762207079, COSV54845867; called by muse, mutect2, varscan2
- ZSWIM4 | c.1079A>T p.Q360L | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.073); catalogued as COSV54320148; called by muse, mutect2, varscan2
- HPS4 | c.1769dup p.P591Afs*4 | Frame Shift Ins (INS) | VAF 4/32 reads (13%) | called by mutect2, pindel
- IGKV1D-8 | c.41T>A p.L14Q | Missense Mutation (SNP) | VAF 20/213 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- KDM6A | c.1553_1565del p.V518Efs*26 | Frame Shift Del (DEL) | VAF 26/84 reads (31%) | called by mutect2, pindel, varscan2
- PCDH7 | c.2513C>A p.S838Y | Missense Mutation (SNP) | VAF 28/121 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); called by muse, mutect2, varscan2
- PTPN21 | c.2329_2358del p.V777_P786del | In Frame Del (DEL) | VAF 4/52 reads (8%) | called by mutect2, pindel
- RELN | c.5473dup p.R1825Kfs*7 | Frame Shift Ins (INS) | VAF 37/113 reads (33%) | called by mutect2, pindel, varscan2
- SEMA4A | c.1391del p.P464Lfs*20 | Frame Shift Del (DEL) | VAF 11/111 reads (10%) | called by mutect2, pindel, varscan2
- TRAV13-2 | c.274C>A p.H92N | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- TRAV26-2 | c.142G>C p.D48H | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.465); called by muse, mutect2, varscan2
- AC098582.1 | c.2133G>C p.L711= | Silent (SNP) | VAF 18/79 reads (23%) | catalogued as COSV52018543; called by muse, mutect2, varscan2
- ACP4 | c.1044C>G p.L348= | Silent (SNP) | VAF 54/226 reads (24%) | catalogued as COSV54516501, COSV54519369; called by muse, mutect2, varscan2
- ACTRT1 | c.555G>A p.G185= | Silent (SNP) | VAF 16/86 reads (19%) | catalogued as COSV64419060, COSV64419125; called by muse, mutect2, varscan2
- ADAM22 | c.1056G>A p.L352= | Silent (SNP) | VAF 18/107 reads (17%) | catalogued as COSV55972496; called by muse, mutect2, varscan2
- ADAMTS12 | c.3066C>A p.V1022= | Silent (SNP) | VAF 8/112 reads (7%) | catalogued as COSV61258255; called by muse, mutect2
- ADCY9 | c.2031C>T p.L677= | Silent (SNP) | VAF 16/37 reads (43%) | catalogued as COSV53572871, COSV53578106; called by muse, mutect2, varscan2
- ADGRV1 | c.12744G>C p.L4248= | Silent (SNP) | VAF 6/12 reads (50%) | catalogued as COSV67980857; called by muse, mutect2, varscan2
- AHRR | c.864G>C p.L288= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as rs761363306, COSV57084002; called by muse, mutect2, varscan2
- AKAP9 | c.4266G>A p.V1422= | Silent (SNP) | VAF 10/74 reads (14%) | catalogued as rs1486993423, COSV62341460; ClinVar: likely benign; called by muse, varscan2
- ALG12 | c.138C>T p.L46= | Silent (SNP) | VAF 25/51 reads (49%) | catalogued as COSV58206549; called by muse, mutect2, varscan2
- AP4M1 | c.1284C>T p.F428= | Silent (SNP) | VAF 11/41 reads (27%) | catalogued as rs1443950530, COSV57994659; called by muse, mutect2, varscan2
- ARHGAP31 | c.4320G>A p.G1440= | Silent (SNP) | VAF 7/51 reads (14%) | catalogued as COSV51790376; called by muse, mutect2, varscan2
- ARHGEF26 | c.828C>G p.L276= | Silent (SNP) | VAF 3/18 reads (17%) | catalogued as COSV62852217; called by muse, mutect2
- ARID1A | c.6123G>A p.V2041= | Silent (SNP) | VAF 15/79 reads (19%) | catalogued as COSV61373955; called by muse, mutect2, varscan2
- ARMC3 | c.1383C>G p.L461= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as COSV53058655, COSV99958441; called by muse, mutect2, varscan2
- ATP2B4 | c.96C>T p.L32= | Silent (SNP) | VAF 48/152 reads (32%) | catalogued as COSV58175372, COSV58184476; called by muse, mutect2
- BPIFA3 | c.567C>G p.L189= | Silent (SNP) | VAF 43/139 reads (31%) | catalogued as rs1280619400, COSV64925684; called by muse, mutect2, varscan2
- BPTF | c.5694G>A p.Q1898= | Silent (SNP) | VAF 20/98 reads (20%) | catalogued as COSV58833749, COSV58834539; called by muse, mutect2, varscan2
- C1orf162 | c.54C>G p.L18= | Silent (SNP) | VAF 39/152 reads (26%) | catalogued as COSV59058885; called by muse, mutect2, varscan2
- CACNA1I | c.363C>T p.F121= | Silent (SNP) | VAF 11/45 reads (24%) | catalogued as COSV60803432; called by muse, mutect2, varscan2
- CAV3 | c.396C>G p.L132= | Silent (SNP) | VAF 26/105 reads (25%) | catalogued as COSV57478765; called by muse, mutect2, varscan2
- CAVIN2 | c.318C>G p.S106= | Silent (SNP) | VAF 12/57 reads (21%) | catalogued as COSV58423584; called by muse, mutect2, varscan2
- CCDC63 | c.414C>T p.F138= | Silent (SNP) | VAF 24/152 reads (16%) | catalogued as rs372540201; called by muse, mutect2, varscan2
- CDK11A | c.1404C>T p.I468= (on ENST00000378633 / NM_001313896.2; = p.I465= on NM_024011.4) | Silent (SNP) | VAF 93/258 reads (36%) | catalogued as COSV52306991; called by muse, varscan2
- CEACAM5 | c.2022C>G p.V674= | Silent (SNP) | VAF 20/87 reads (23%) | catalogued as COSV55751220; called by muse, mutect2, varscan2
- CFAP74 | c.4536G>A p.L1512= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as rs748998655; called by muse, varscan2
- CHD5 | c.4035C>T p.I1345= | Silent (SNP) | VAF 22/53 reads (42%) | catalogued as COSV52410430; called by muse, mutect2, varscan2
- CILP | c.1467G>T p.R489= | Silent (SNP) | VAF 13/52 reads (25%) | catalogued as COSV56022727, COSV99973814; called by muse, mutect2, varscan2
- CKB | c.171C>T p.I57= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as rs1284171831, COSV62379412; called by muse, varscan2
- CLBA1 | c.93G>C p.L31= | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as COSV66347893; called by muse, mutect2, varscan2
- CLCN5 | c.1548G>T p.R516= | Silent (SNP) | VAF 51/264 reads (19%) | catalogued as COSV56582954; called by muse, mutect2, varscan2
- COL16A1 | c.2571C>T p.L857= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as COSV54701853, COSV54702316; called by muse, varscan2
- COL1A2 | c.3384C>G p.L1128= | Silent (SNP) | VAF 11/56 reads (20%) | catalogued as COSV51955010, COSV51966986; called by muse, mutect2, varscan2
- COL4A5 | c.5049G>A p.K1683= | Silent (SNP) | VAF 19/74 reads (26%) | catalogued as COSV60358291; called by muse, mutect2, varscan2
- CORIN | c.1326C>T p.L442= | Silent (SNP) | VAF 38/85 reads (45%) | catalogued as COSV56688432; called by muse, mutect2, varscan2
- COX11 | c.319C>T p.L107= | Silent (SNP) | VAF 17/41 reads (41%) | catalogued as rs950499638, COSV54802600; called by muse, mutect2, varscan2
- CRACDL | c.1350G>A p.E450= | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as COSV67407097; called by muse, mutect2, varscan2
- CRISPLD1 | c.612C>T p.C204= | Silent (SNP) | VAF 13/57 reads (23%) | catalogued as COSV51545675; called by muse, mutect2, varscan2
- CRMP1 | c.637C>T p.L213= | Silent (SNP) | VAF 18/72 reads (25%) | catalogued as COSV61478879; called by muse, mutect2, varscan2
- CRTC1 | c.531G>A p.Q177= | Silent (SNP) | VAF 12/43 reads (28%) | catalogued as COSV100119462, COSV58717245; called by muse, mutect2
- CSMD3 | c.9747C>T p.F3249= (on ENST00000297405 / NM_001363185.1; = p.F3080= on NM_052900.3) | Silent (SNP) | VAF 16/73 reads (22%) | catalogued as rs61754530, COSV52091126; called by muse, mutect2, varscan2
- DDX19B | c.171T>G p.A57= | Silent (SNP) | VAF 47/182 reads (26%) | catalogued as COSV55363137; called by muse, mutect2
- DENND4A | c.549C>G p.L183= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as COSV71265443; called by muse, mutect2, varscan2
- DIMT1 | c.684G>A p.R228= | Silent (SNP) | VAF 13/77 reads (17%) | catalogued as COSV52233090; called by muse, mutect2, varscan2
- DMBT1 | c.6378C>T p.L2126= (on ENST00000338354 / NM_001377530.1; = p.L1369= on NM_004406.3) | Silent (SNP) | VAF 5/13 reads (38%) | catalogued as COSV100353645; called by muse, mutect2, varscan2
- DNAJC22 | c.534C>T p.L178= | Silent (SNP) | VAF 16/70 reads (23%) | catalogued as COSV67711592; called by muse, mutect2, varscan2
- DOP1A | c.3423G>A p.K1141= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as rs1562345752, COSV52708173; called by muse, mutect2, varscan2
- DRG2 | c.510C>T p.L170= | Silent (SNP) | VAF 17/80 reads (21%) | catalogued as COSV56727971; called by muse, mutect2, varscan2
- EIF4ENIF1 | c.2289G>A p.Q763= | Silent (SNP) | VAF 15/112 reads (13%) | catalogued as rs369647505, COSV57517371; called by muse, mutect2, varscan2
- EPHA5 | c.2826G>A p.L942= | Silent (SNP) | VAF 12/104 reads (12%) | catalogued as rs1321079759, COSV56636545; called by muse, mutect2, varscan2
- EPHA8 | c.2025G>A p.E675= | Silent (SNP) | VAF 32/79 reads (41%) | catalogued as rs373953943, COSV51264737; called by muse, mutect2, varscan2
- EWSR1 | c.189G>A p.Q63= | Silent (SNP) | VAF 23/63 reads (37%) | catalogued as COSV58422414; called by muse, mutect2, varscan2
- FAM122B | c.537C>G p.L179= (on ENST00000370790 / NM_001166599.3; = p.L180= on NM_145284.5) | Silent (SNP) | VAF 45/143 reads (31%) | catalogued as COSV53230797; called by muse, mutect2, varscan2
- FAM171B | c.840G>C p.L280= | Silent (SNP) | VAF 24/116 reads (21%) | catalogued as COSV59000323, COSV59001667; called by muse, mutect2, varscan2
- FAM214A | c.489G>A p.L163= | Silent (SNP) | VAF 20/63 reads (32%) | catalogued as COSV55922905, COSV99958692; called by muse, mutect2, varscan2
- FRMD3 | c.1044C>A p.I348= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as COSV58456890, COSV58465762; called by muse, mutect2, varscan2
- FRMPD4 | c.3705G>A p.V1235= | Silent (SNP) | VAF 36/140 reads (26%) | catalogued as COSV66212588; called by muse, mutect2, varscan2
- FTSJ3 | c.99C>A p.I33= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as rs761636452, COSV59561819; called by muse, mutect2, varscan2
- FUT2 | c.1002C>T p.A334= | Silent (SNP) | VAF 15/75 reads (20%) | catalogued as rs144809245; called by muse, mutect2, varscan2
- GABBR1 | c.1029C>T p.F343= | Silent (SNP) | VAF 14/39 reads (36%) | catalogued as COSV100589550, COSV63541598; called by muse, mutect2, varscan2
- GON4L | c.1317C>T p.I439= | Silent (SNP) | VAF 17/66 reads (26%) | catalogued as rs1224473245, COSV55189619; called by muse, mutect2, varscan2
- GPR101 | c.147C>T p.N49= | Silent (SNP) | VAF 28/116 reads (24%) | catalogued as COSV53237891; called by muse, mutect2, varscan2
- GPR137 | c.534G>A p.V178= | Silent (SNP) | VAF 12/50 reads (24%) | catalogued as COSV57401426, COSV57403498; called by muse, mutect2, varscan2
- GPR37L1 | c.744C>T p.I248= | Silent (SNP) | VAF 15/61 reads (25%) | catalogued as COSV66161993; called by muse, mutect2, varscan2
- GRIK3 | c.576C>T p.I192= | Silent (SNP) | VAF 12/76 reads (16%) | catalogued as COSV66137075; called by muse, mutect2
- H2AC16 | c.282C>T p.L94= | Silent (SNP) | VAF 12/141 reads (9%) | catalogued as COSV58899466; called by muse, mutect2
- HSPG2 | c.5496G>C p.L1832= | Silent (SNP) | VAF 60/131 reads (46%) | catalogued as COSV65969990; called by muse, mutect2, varscan2
- IDI2 | c.123G>C p.L41= | Silent (SNP) | VAF 10/58 reads (17%) | catalogued as COSV52987360; called by muse, varscan2
- IGF2BP3 | c.1143G>A p.G381= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as rs1006615168, COSV99325640; called by muse, mutect2
- IGKV2-30 | c.189G>A p.Q63= | Silent (SNP) | VAF 19/196 reads (10%) | called by muse, mutect2, varscan2
- IL1RAP | c.492T>C p.D164= | Silent (SNP) | VAF 33/107 reads (31%) | catalogued as COSV50759785; called by muse, mutect2, varscan2
- INCENP | c.147C>T p.F49= | Silent (SNP) | VAF 7/35 reads (20%) | catalogued as rs867025091, COSV53914186; called by muse, mutect2, varscan2
- IQCJ-SCHIP1 | c.1674G>A p.E558= (on ENST00000485419 / NM_001197113.1; = p.E482= on NM_014575.3) | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as COSV61841027; called by muse, mutect2, varscan2
- IRF3 | c.123C>T p.G41= | Silent (SNP) | VAF 62/140 reads (44%) | catalogued as rs780911464, COSV55862647; called by muse, mutect2, varscan2
- IRF5 | c.1011C>T p.I337= | Silent (SNP) | VAF 10/96 reads (10%) | catalogued as rs1563078213, COSV50857034; called by muse, mutect2
- JAG1 | c.549C>A p.I183= | Silent (SNP) | VAF 8/80 reads (10%) | catalogued as COSV54754768; called by muse, mutect2
- KCNJ4 | c.45G>A p.R15= | Silent (SNP) | VAF 47/281 reads (17%) | catalogued as rs1160398087, COSV57856478; called by muse, mutect2, varscan2
- KCNU1 | c.2778G>T p.L926= | Silent (SNP) | VAF 14/82 reads (17%) | catalogued as COSV67754199; called by muse, mutect2, varscan2
- KIAA0232 | c.600C>G p.V200= | Silent (SNP) | VAF 15/92 reads (16%) | catalogued as COSV56923970; called by muse, mutect2, varscan2
- KIF6 | c.2130C>G p.L710= | Silent (SNP) | VAF 15/84 reads (18%) | catalogued as COSV54671171; called by muse, mutect2, varscan2
- LARS2 | c.720A>G p.Q240= | Silent (SNP) | VAF 5/87 reads (6%) | catalogued as rs930522478, COSV99648089; called by muse, mutect2
- LDOC1 | c.39G>A p.L13= | Silent (SNP) | VAF 6/13 reads (46%) | catalogued as COSV100983187, COSV65159080; called by muse, mutect2, varscan2
- LIPE | c.2643G>C p.L881= | Silent (SNP) | VAF 12/63 reads (19%) | catalogued as COSV54921940; called by muse, mutect2, varscan2
- LRRC32 | c.1269C>T p.S423= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as COSV99477127; called by muse, mutect2, varscan2
- LRRC37A3 | c.1071C>T p.I357= | Silent (SNP) | VAF 53/241 reads (22%) | catalogued as rs1336513815, COSV100140973, COSV59760619; called by muse, mutect2, varscan2
- LRRC8E | c.924C>G p.L308= | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as COSV60717281; called by muse, mutect2, varscan2
- LYPD4 | c.54C>T p.I18= | Silent (SNP) | VAF 8/92 reads (9%) | called by muse, mutect2
- MAB21L4 | c.537G>A p.L179= (on ENST00000388934 / NM_001085437.3; = p.L11= on NM_024861.4) | Silent (SNP) | VAF 17/47 reads (36%) | catalogued as COSV56742971; called by muse, mutect2, varscan2
- MCTP1 | c.1965G>C p.L655= | Silent (SNP) | VAF 19/54 reads (35%) | catalogued as rs200911443; called by muse, mutect2, varscan2
- MEAK7 | c.846C>G p.L282= | Silent (SNP) | VAF 9/43 reads (21%) | catalogued as rs150857959; called by muse, mutect2, varscan2
- MST1 | c.885C>T p.V295= | Silent (SNP) | VAF 14/49 reads (29%) | catalogued as COSV56532687; called by muse, mutect2, varscan2
- MUC16 | c.2034C>G p.V678= | Silent (SNP) | VAF 32/81 reads (40%) | catalogued as COSV67453437; called by muse, mutect2, varscan2
- MUC4 | c.1992C>T p.V664= | Silent (SNP) | VAF 56/104 reads (54%) | catalogued as COSV62138173; called by muse, mutect2, varscan2
- MUC5B | c.13530G>T p.L4510= | Silent (SNP) | VAF 30/168 reads (18%) | catalogued as rs1270189458, COSV71590619; called by muse, mutect2, varscan2
- MYCBP2 | c.12114C>T p.S4038= (on ENST00000357337; = p.S4076= on NM_015057.5) | Silent (SNP) | VAF 29/81 reads (36%) | catalogued as COSV62012946; called by muse, mutect2, varscan2
- NCAPH | c.1056C>T p.I352= | Silent (SNP) | VAF 19/162 reads (12%) | catalogued as COSV53635566; called by muse, mutect2, varscan2
- NECAB3 | c.888C>T p.L296= (on ENST00000246190 / NM_031232.4; = p.L262= on NM_031231.4) | Silent (SNP) | VAF 3/21 reads (14%) | catalogued as rs1161110840, COSV99864980; called by muse, mutect2
- NEUROD1 | c.363A>G p.L121= | Silent (SNP) | VAF 31/77 reads (40%) | catalogued as rs746977592, COSV54548505; called by muse, mutect2, varscan2
- NF2 | c.984G>A p.E328= | Silent (SNP) | VAF 11/27 reads (41%) | catalogued as CX070571, COSV100098920; called by muse, mutect2, varscan2
- NFYC | c.1376G>A p.*459= (on ENST00000308733 / NM_001308114.1; = p.*336= on NM_014223.5) | Silent (SNP) | VAF 5/49 reads (10%) | catalogued as rs1270233238, COSV58125476; called by muse, mutect2
- NID1 | c.1932G>A p.Q644= | Silent (SNP) | VAF 9/210 reads (4%) | catalogued as rs1465844700, COSV51616809; called by muse, mutect2
- NKRF | c.654T>C p.Y218= | Silent (SNP) | VAF 22/117 reads (19%) | catalogued as COSV58661011; called by muse, mutect2, varscan2
- NLRP12 | c.99G>A p.G33= | Silent (SNP) | VAF 11/77 reads (14%) | catalogued as COSV60744848; called by muse, mutect2, varscan2
- NSD3 | c.4026C>G p.P1342= | Silent (SNP) | VAF 4/88 reads (5%) | catalogued as COSV100395497; called by muse, mutect2
- NUMA1 | c.790C>T p.L264= | Silent (SNP) | VAF 5/28 reads (18%) | catalogued as COSV61184067; called by muse, mutect2, varscan2
- OCRL | c.2013C>T p.I671= | Silent (SNP) | VAF 30/88 reads (34%) | catalogued as COSV63980502, COSV63981106; called by muse, mutect2, varscan2
- OR2L13 | c.426G>A p.K142= | Silent (SNP) | VAF 68/216 reads (31%) | catalogued as COSV63550000, COSV63551649; called by muse, mutect2, varscan2
- OR4C16 | c.141C>G p.V47= | Silent (SNP) | VAF 46/155 reads (30%) | catalogued as rs748251115, COSV58941220; called by muse, mutect2, varscan2
- OR51D1 | c.522C>T p.F174= | Silent (SNP) | VAF 21/83 reads (25%) | catalogued as COSV62913998; called by muse, mutect2, varscan2
- OR52K1 | c.684C>A p.L228= | Silent (SNP) | VAF 31/161 reads (19%) | catalogued as rs765929883, COSV56903309; called by muse, mutect2, varscan2
- OR5D14 | c.849C>T p.V283= | Silent (SNP) | VAF 12/72 reads (17%) | catalogued as COSV59455758; called by muse, mutect2, varscan2
- OR6K6 | c.411C>T p.I137= (on ENST00000368144; = p.I113= on NM_001005184.1) | Silent (SNP) | VAF 16/74 reads (22%) | catalogued as COSV63743760; called by muse, mutect2, varscan2
- OR9G4 | c.876G>A p.L292= | Silent (SNP) | VAF 17/131 reads (13%) | catalogued as COSV57248069; called by muse, mutect2, varscan2
- OVCH1 | c.3225T>C p.F1075= | Silent (SNP) | VAF 15/32 reads (47%) | catalogued as COSV100548967; called by muse, mutect2, varscan2
- PACSIN2 | c.561C>T p.L187= | Silent (SNP) | VAF 13/160 reads (8%) | catalogued as COSV54317401; called by muse, mutect2
- PADI6 | c.651G>C p.S217= | Silent (SNP) | VAF 26/85 reads (31%) | catalogued as COSV61883960; called by muse, mutect2, varscan2
- PCCB | c.639C>T p.F213= | Silent (SNP) | VAF 9/68 reads (13%) | catalogued as COSV52444023; called by muse, mutect2, varscan2
- PCDHB12 | c.2097G>A p.S699= | Silent (SNP) | VAF 30/112 reads (27%) | catalogued as rs1195588413, COSV53394231; called by muse, mutect2, varscan2
- PCNA | c.636G>A p.L212= | Silent (SNP) | VAF 16/123 reads (13%) | catalogued as COSV52531852; called by muse, mutect2, varscan2
- PCYT1A | c.942C>T p.I314= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as rs1203948739, COSV99492340; called by muse, mutect2
- PDCD11 | c.510G>A p.L170= | Silent (SNP) | VAF 18/51 reads (35%) | catalogued as COSV63933351; called by muse, mutect2, varscan2
- PDE4DIP | c.5700C>G p.L1900= | Silent (SNP) | VAF 89/233 reads (38%) | catalogued as COSV57684417; called by muse, mutect2, varscan2
- PDGFC | c.78G>A p.L26= | Silent (SNP) | VAF 12/51 reads (24%) | catalogued as COSV56846733; called by muse, mutect2, varscan2
- PLXNA1 | c.3018G>A p.R1006= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as COSV52523576; called by muse, mutect2, varscan2
- POLQ | c.7497C>T p.F2499= | Silent (SNP) | VAF 19/80 reads (24%) | catalogued as COSV51748060; called by muse, mutect2, varscan2
- PPRC1 | c.765C>T p.F255= | Silent (SNP) | VAF 16/52 reads (31%) | catalogued as COSV53383999; called by muse, mutect2, varscan2
- PRAMEF4 | c.1203G>C p.L401= | Silent (SNP) | VAF 126/410 reads (31%) | catalogued as COSV52437776; called by mutect2, varscan2
- PRR5-ARHGAP8 | c.1230C>G p.L410= (on ENST00000352766; = p.L331= on NM_181334.5) | Silent (SNP) | VAF 23/39 reads (59%) | catalogued as COSV61232148; called by muse, mutect2, varscan2
- PTPRU | c.3777C>G p.P1259= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as COSV60523913; called by muse, mutect2, varscan2
- RAD21 | c.1488G>A p.Q496= | Silent (SNP) | VAF 10/103 reads (10%) | catalogued as COSV99815471; called by muse, mutect2
- RALGAPB | c.2778G>A p.V926= | Silent (SNP) | VAF 22/129 reads (17%) | catalogued as COSV53435775; called by muse, mutect2, varscan2
- RBBP4 | c.918G>A p.L306= | Silent (SNP) | VAF 22/82 reads (27%) | catalogued as rs1423135647, COSV65132215; called by muse, varscan2
- REXO2 | c.108G>A p.G36= | Silent (SNP) | VAF 4/21 reads (19%) | catalogued as COSV99771778; called by muse, mutect2
- RILPL2 | c.588G>A p.K196= | Silent (SNP) | VAF 12/66 reads (18%) | catalogued as COSV54912133; called by muse, varscan2
- RNF20 | c.474C>T p.F158= | Silent (SNP) | VAF 22/64 reads (34%) | catalogued as COSV66355559; called by muse, mutect2, varscan2
- RPL31 | c.130C>A p.R44= | Silent (SNP) | VAF 15/80 reads (19%) | catalogued as COSV51821182, COSV51822752; called by muse, mutect2, varscan2
- SBNO2 | c.2676C>T p.L892= | Silent (SNP) | VAF 10/77 reads (13%) | catalogued as COSV62319281; called by muse, mutect2, varscan2
- SCN10A | c.5136C>T p.I1712= | Silent (SNP) | VAF 28/111 reads (25%) | catalogued as rs757792173, COSV71860724, COSV71862422; called by muse, mutect2, varscan2
- SLC2A8 | c.1207C>T p.L403= | Silent (SNP) | VAF 16/52 reads (31%) | catalogued as COSV64894251; called by muse, mutect2, varscan2
- SLC45A1 | c.880C>A p.R294= | Silent (SNP) | VAF 18/54 reads (33%) | catalogued as COSV57093836; called by muse, mutect2, varscan2
- SLC4A3 | c.879C>T p.G293= | Silent (SNP) | VAF 14/55 reads (25%) | catalogued as rs201306555, COSV56092189; called by muse, mutect2, varscan2
- SLC4A5 | c.486C>G p.L162= | Silent (SNP) | VAF 15/94 reads (16%) | catalogued as COSV61025797; called by muse, mutect2, varscan2
- SLC52A2 | c.33G>A p.L11= | Silent (SNP) | VAF 10/33 reads (30%) | catalogued as COSV57351213; called by muse, mutect2, varscan2
- SLC6A2 | c.216C>T p.F72= | Silent (SNP) | VAF 18/84 reads (21%) | catalogued as COSV54914595; called by muse, mutect2, varscan2
- SMARCA2 | c.3372G>A p.L1124= | Silent (SNP) | VAF 17/70 reads (24%) | catalogued as COSV61805521; called by muse, mutect2, varscan2
- SNX31 | c.969C>T p.V323= | Silent (SNP) | VAF 17/49 reads (35%) | catalogued as COSV61262325; called by muse, varscan2
- SNX31 | c.903C>A p.I301= | Silent (SNP) | VAF 40/85 reads (47%) | catalogued as COSV100309847, COSV61262334; called by muse, varscan2
- STK3 | c.588A>T p.I196= | Silent (SNP) | VAF 41/136 reads (30%) | catalogued as COSV69222464; called by muse, mutect2, varscan2
- STK32B | c.273G>A p.Q91= | Silent (SNP) | VAF 15/56 reads (27%) | catalogued as COSV51477901; called by muse, mutect2, varscan2
- SULT1B1 | c.318G>A p.V106= | Silent (SNP) | VAF 19/71 reads (27%) | catalogued as rs1412266505, COSV60206751; called by muse, mutect2, varscan2
- SYT14 | c.774A>G p.E258= | Silent (SNP) | VAF 33/107 reads (31%) | catalogued as COSV55050749; called by muse, varscan2
- TBC1D23 | c.664C>T p.L222= | Silent (SNP) | VAF 39/93 reads (42%) | catalogued as COSV61367249, COSV61368619; called by muse, mutect2, varscan2
- TEAD4 | c.201C>T p.I67= | Silent (SNP) | VAF 7/90 reads (8%) | catalogued as COSV63280325; called by muse, mutect2
- TENM1 | c.2529C>G p.L843= | Silent (SNP) | VAF 15/76 reads (20%) | catalogued as COSV64427653; called by muse, mutect2, varscan2
- TICAM1 | c.1332C>T p.D444= | Silent (SNP) | VAF 7/44 reads (16%) | catalogued as rs773404292, COSV50230316; called by muse, mutect2, varscan2
- TKT | c.309C>T p.I103= | Silent (SNP) | VAF 18/46 reads (39%) | catalogued as rs1176397680, COSV56244736; called by muse, mutect2, varscan2
- TLE1 | c.1734C>T p.Y578= | Silent (SNP) | VAF 14/78 reads (18%) | catalogued as rs764412759, COSV64719249; called by muse, mutect2, varscan2
- TMC2 | c.1536C>G p.L512= | Silent (SNP) | VAF 9/65 reads (14%) | catalogued as COSV100727777; called by muse, mutect2
- TMEM181 | c.423C>T p.V141= | Silent (SNP) | VAF 20/76 reads (26%) | catalogued as rs1221420000, COSV65562495; called by muse, mutect2, varscan2
- TMEM185A | c.756C>G p.L252= | Silent (SNP) | VAF 8/50 reads (16%) | called by muse, mutect2, varscan2
- TMEM26 | c.141C>T p.F47= | Silent (SNP) | VAF 10/68 reads (15%) | catalogued as COSV67492616; called by muse, mutect2, varscan2
- TONSL | c.1137G>C p.L379= | Silent (SNP) | VAF 12/51 reads (24%) | catalogued as COSV68047907; called by muse, mutect2, varscan2
- TOP3B | c.1215G>A p.A405= | Silent (SNP) | VAF 9/43 reads (21%) | catalogued as rs376875913; ClinVar: likely benign; called by muse, mutect2, varscan2
- TPTE | c.999C>T p.I333= (on ENST00000618007 / NM_199261.4; = p.I315= on NM_199259.4) | Silent (SNP) | VAF 27/130 reads (21%) | catalogued as rs759012135; called by muse, mutect2, varscan2
- TRIM67 | c.1389G>A p.L463= | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as COSV100792168; called by muse, mutect2, varscan2
- TRMT2B | c.282G>A p.L94= | Silent (SNP) | VAF 19/61 reads (31%) | catalogued as COSV58618819; called by muse, mutect2, varscan2
- TSC22D3 | c.195G>C p.L65= | Silent (SNP) | VAF 13/103 reads (13%) | catalogued as COSV100227011, COSV59777336; called by muse, mutect2, varscan2
- TTN | c.51291C>G p.V17097= (on ENST00000591111; = p.V9673= on NM_003319.4) | Silent (SNP) | VAF 44/109 reads (40%) | catalogued as COSV59945029; called by muse, mutect2, varscan2
- USP32 | c.1539G>A p.L513= | Silent (SNP) | VAF 16/126 reads (13%) | catalogued as COSV56265890; called by muse, mutect2, varscan2
- WWC3 | c.501G>A p.L167= | Silent (SNP) | VAF 16/57 reads (28%) | catalogued as COSV66502090; called by muse, mutect2, varscan2
- WWP2 | c.1968C>G p.V656= | Silent (SNP) | VAF 19/61 reads (31%) | catalogued as COSV63123910; called by muse, mutect2, varscan2
- ZBED9 | c.621C>T p.L207= | Silent (SNP) | VAF 21/48 reads (44%) | catalogued as COSV71729243; called by muse, mutect2, varscan2
- ZC3HAV1 | c.531C>T p.F177= | Silent (SNP) | VAF 9/48 reads (19%) | catalogued as rs1309224691, COSV54294327; called by muse, mutect2, varscan2
- ZCCHC24 | c.345G>A p.L115= | Silent (SNP) | VAF 14/38 reads (37%) | catalogued as COSV64886392; called by muse, mutect2, varscan2
- ZFYVE28 | c.1224G>T p.G408= | Silent (SNP) | VAF 20/61 reads (33%) | catalogued as rs1450220190, COSV52108854; called by muse, mutect2, varscan2
- ZIM2 | c.1095C>T p.F365= | Silent (SNP) | VAF 68/169 reads (40%) | catalogued as COSV55628784; called by muse, mutect2, varscan2
- ZKSCAN4 | c.690C>G p.L230= | Silent (SNP) | VAF 30/65 reads (46%) | catalogued as COSV66023201; called by muse, mutect2, varscan2
- ZNF436 | c.1281C>T p.F427= | Silent (SNP) | VAF 50/168 reads (30%) | catalogued as COSV58358254; called by muse, mutect2, varscan2
- ZNF84 | c.258T>A p.G86= | Silent (SNP) | VAF 14/68 reads (21%) | called by muse, mutect2, varscan2
- AC245047.1 | n.124G>A | RNA (SNP) | VAF 27/155 reads (17%) | catalogued as rs782680983; called by muse, mutect2, varscan2
- AL353804.6 | chrX:73827254 C>A | 3'Flank (SNP) | VAF 33/154 reads (21%) | called by muse, mutect2, varscan2
- AL353804.7 | chrX:73851365 G>A | 3'Flank (SNP) | VAF 23/216 reads (11%) | called by muse, mutect2, varscan2
- ALDH9A1 | c.-1C>G | 5'UTR (SNP) | VAF 9/19 reads (47%) | catalogued as rs1360719807, COSV100699318; called by muse, mutect2, varscan2
- CEP295 | c.5851-159C>G | Intron (SNP) | VAF 35/88 reads (40%) | catalogued as COSV100292575; called by muse, mutect2, varscan2
- CEP295 | chr11:93735132 C>G | 3'Flank (SNP) | VAF 7/42 reads (17%) | called by muse, mutect2, varscan2
- CLLU1 | chr12:92421079 C>G | 5'Flank (SNP) | VAF 69/192 reads (36%) | catalogued as COSV65902900; called by muse, mutect2, varscan2
- ERCC2 | c.1238-1171C>G | Intron (SNP) | VAF 13/46 reads (28%) | catalogued as COSV55539567; called by muse, mutect2, varscan2
- ERCC6 | c.1397+8241G>A | Intron (SNP) | VAF 25/119 reads (21%) | catalogued as COSV63388614; called by muse, mutect2, varscan2
- GATA3 | chr10:8050873 C>T | 5'Flank (SNP) | VAF 6/10 reads (60%) | catalogued as rs763859093; called by muse, varscan2
- GZF1 | c.-1G>C | 5'UTR (SNP) | VAF 10/59 reads (17%) | catalogued as COSV100582610; called by muse, mutect2, varscan2
- MATK | chr19:3789326 C>T | 5'Flank (SNP) | VAF 8/32 reads (25%) | catalogued as COSV59553630; called by muse, mutect2, varscan2
- NACA | c.70+4584G>A | Intron (SNP) | VAF 11/27 reads (41%) | catalogued as COSV63268547; called by muse, mutect2, varscan2
- NBPF7 | n.506G>A | RNA (SNP) | VAF 24/179 reads (13%) | catalogued as rs377474156; called by muse, mutect2, varscan2
- PLOD1 | c.741+149C>G | Intron (SNP) | VAF 52/182 reads (29%) | catalogued as COSV52142047; called by muse, mutect2, varscan2
- PPP2R1B | chr11:111737532 C>T | 3'Flank (SNP) | VAF 16/64 reads (25%) | catalogued as COSV59535013; called by muse, mutect2, varscan2
- RNF217-AS1 | n.3095C>G | RNA (SNP) | VAF 4/20 reads (20%) | called by muse, mutect2
- RUBCN | c.*506G>C | 3'UTR (SNP) | VAF 9/112 reads (8%) | catalogued as COSV99584638; called by muse, mutect2
8 further variants in this file (0 protein-altering or splice-affecting, 0 silent, 8 other) are not listed here.
